Somatic mutation profile of tumor specimen TCGA-33-4566-01A (aliquot TCGA-33-4566-01A-01D-1441-08) from TCGA case TCGA-33-4566, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 40.1 years (14,643 days).
Specimen TCGA-33-4566-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 30b8d398-62d0-42c5-b446-343427501160.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-33-4566-11A (Solid Tissue Normal), aliquot TCGA-33-4566-11A-01D-1441-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e12b4544-e0bf-41de-a235-48a7a75bc8ed

The open-access MAF lists 1,478 somatic variants for this specimen: 1,136 protein-altering or splice-affecting, 301 silent, 41 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 958, Silent 301, Nonsense Mutation 88, Splice Site 31, Frame Shift Del 31, RNA 17, Frame Shift Ins 13, Splice Region 12, Intron 8, 5'Flank 6, 3'Flank 5, 5'UTR 3.

Variants (750 of 1,478; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.490A>G p.K164E | Missense Mutation (SNP) | VAF 42/83 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs879254249, COSV52676020, COSV52700231, COSV52728094, COSV52766542; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AADACL2 | c.564C>G p.D188E | Missense Mutation (SNP) | VAF 25/212 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.85); catalogued as COSV62932458; called by muse, mutect2, varscan2
- AAK1 | c.299A>T p.H100L | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV68646657; called by muse, mutect2, varscan2
- AASS | c.1603A>T p.K535* | Nonsense Mutation (SNP) | VAF 11/68 reads (16%) | catalogued as COSV62791775; called by muse, varscan2
- AASS | c.1585G>T p.V529F | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as COSV62791782; called by muse, varscan2
- AASS | c.117G>T p.R39S | Missense Mutation (SNP) | VAF 39/127 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62791786; called by muse, mutect2, varscan2
- ABCA1 | c.3862G>T p.D1288Y | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); catalogued as COSV66070622; called by muse, mutect2, varscan2
- ABCA12 | c.1550T>A p.L517Q (on ENST00000272895 / NM_173076.3; = p.L199Q on NM_015657.3) | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0.069); catalogued as COSV55975453; called by muse, mutect2, varscan2
- ABCA13 | c.7229G>T p.G2410V | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV71294300; called by muse, mutect2, varscan2
- ABCA13 | c.12243G>T p.E4081D | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV71294304; called by muse, varscan2
- ABCA2 | c.3728A>G p.Y1243C (on ENST00000614293; = p.Y1213C on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV55806693; called by muse, mutect2, varscan2
- ABCA4 | c.3609G>T p.G1203= | Splice Region (SNP) | VAF 29/101 reads (29%) | catalogued as COSV64678057; called by muse, mutect2, varscan2
- ABCA8 | c.1988A>T p.K663M | Missense Mutation (SNP) | VAF 63/251 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52198605; called by muse, mutect2, varscan2
- ABCA9 | c.4160C>A p.A1387D | Missense Mutation (SNP) | VAF 47/164 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV60631059, COSV60631958; called by muse, mutect2, varscan2
- ABCA9 | c.4159G>A p.A1387T | Missense Mutation (SNP) | VAF 45/159 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.957); catalogued as rs763208154, COSV60620742; called by muse, mutect2, varscan2
- ABCA9 | c.2962G>C p.D988H | Missense Mutation (SNP) | VAF 38/158 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV60631082; called by muse, mutect2, varscan2
- ABLIM1 | c.247G>T p.A83S | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV53315821; called by muse, mutect2, varscan2
- ACKR1 | c.886C>A p.H296N | Missense Mutation (SNP) | VAF 191/624 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63674574; called by muse, mutect2, varscan2
- ACOX1 | c.865G>T p.A289S | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV53136631; called by muse, mutect2, varscan2
- ACTBL2 | c.515T>A p.L172Q | Missense Mutation (SNP) | VAF 57/119 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV70661803; called by muse, mutect2, varscan2
- ACTC1 | c.1042C>A p.L348M | Missense Mutation (SNP) | VAF 35/201 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.21); catalogued as COSV51761529; called by muse, mutect2, varscan2
- ADAM21 | c.875A>T p.H292L | Missense Mutation (SNP) | VAF 75/208 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as COSV50800037; called by muse, mutect2, varscan2
- ADAM33 | c.170A>C p.E57A | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.42); PolyPhen benign (0.266); catalogued as rs1193059915, COSV62936911; called by muse, mutect2, varscan2
- ADAMTS12 | c.193C>A p.H65N | Missense Mutation (SNP) | VAF 101/306 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.21); catalogued as COSV61279575; called by muse, mutect2, varscan2
- ADAMTS13 | c.1710T>A p.Y570* | Nonsense Mutation (SNP) | VAF 39/208 reads (19%) | catalogued as COSV63023125; called by muse, mutect2, varscan2
- ADAMTS16 | c.2546C>A p.P849Q | Missense Mutation (SNP) | VAF 39/154 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as rs755952454, COSV57001956, COSV57007028; called by muse, mutect2, varscan2
- ADAMTS18 | c.2710C>A p.Q904K | Missense Mutation (SNP) | VAF 77/151 reads (51%) | SIFT tolerated (0.29); PolyPhen benign (0.017); catalogued as COSV51398936, COSV51423078; called by muse, mutect2, varscan2
- ADAMTS4 | c.2120C>T p.A707V | Missense Mutation (SNP) | VAF 34/232 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.06); catalogued as rs774912153, COSV63489245; called by muse, varscan2
- ADAR | c.889G>T p.A297S | Missense Mutation (SNP) | VAF 61/226 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV52720908, COSV52721380; called by muse, mutect2, varscan2
- ADARB2 | c.117G>T p.L39F | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV67237258; called by muse, mutect2, varscan2
- ADCY10 | c.3853C>A p.L1285I | Missense Mutation (SNP) | VAF 100/349 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.629); catalogued as COSV63244887; called by muse, mutect2, varscan2
- ADCY2 | c.1401G>T p.K467N | Missense Mutation (SNP) | VAF 54/158 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.468); catalogued as COSV57900308; called by muse, mutect2, varscan2
- ADCY2 | c.1477C>A p.R493S | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.465); catalogued as COSV57874000, COSV57900327; called by muse, mutect2, varscan2
- ADCY2 | c.2257G>T p.V753L | Missense Mutation (SNP) | VAF 149/404 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.143); catalogued as COSV57879555, COSV57882172; called by muse, mutect2, varscan2
- ADCY8 | c.1292C>A p.S431Y | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV53927119, COSV99650847; called by muse, mutect2
- ADCY8 | c.1084C>A p.R362S | Missense Mutation (SNP) | VAF 57/320 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as COSV53920853; called by muse, mutect2, varscan2
- ADGRB1 | c.1504G>A p.A502T | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.671); catalogued as COSV60103413; called by muse, mutect2, varscan2
- ADGRB2 | c.3899G>T p.G1300V | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV57078890; called by muse, mutect2, varscan2
- ADGRB3 | c.3905G>T p.R1302I | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.367); catalogued as COSV53257525, COSV53260206; called by muse, mutect2, varscan2
- ADGRB3 | c.4273G>T p.E1425* | Nonsense Mutation (SNP) | VAF 16/37 reads (43%) | catalogued as COSV53260210; called by muse, mutect2, varscan2
- ADGRE2 | c.745G>T p.G249* | Nonsense Mutation (SNP) | VAF 45/193 reads (23%) | catalogued as COSV100216525; called by muse, mutect2, varscan2
- ADGRG4 | c.5599G>T p.G1867* | Nonsense Mutation (SNP) | VAF 89/131 reads (68%) | catalogued as COSV54966625; called by muse, mutect2, varscan2
- ADGRG5 | c.1440C>A p.F480L | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT tolerated (0.22); PolyPhen benign (0.04); catalogued as COSV61084587; called by muse, mutect2, varscan2
- ADGRG6 | c.1793G>T p.G598V | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); catalogued as COSV51600970; called by muse, mutect2, varscan2
- ADGRL4 | c.1697C>A p.T566N | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV66065933; called by muse, mutect2, varscan2
- ADGRV1 | c.10490A>T p.Q3497L | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV67995365; called by muse, mutect2, varscan2
- ADH1A | c.496C>A p.P166T | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52926193; called by muse, mutect2, varscan2
- ADRA1A | c.1240A>G p.K414E | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0.01); catalogued as COSV52373884; called by muse, mutect2, varscan2
- ADRA2B | c.1224C>G p.F408L | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV101337391; called by muse, mutect2, varscan2
- ADRA2B | c.488A>T p.Q163L | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.27); catalogued as COSV69788335; called by muse, mutect2, varscan2
- ADSS2 | c.1118A>T p.K373I | Missense Mutation (SNP) | VAF 43/147 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV63696247; called by muse, mutect2, varscan2
- AFF3 | c.1091+1G>A p.X364_splice | Splice Site (SNP) | VAF 20/88 reads (23%) | catalogued as COSV57873239; called by muse, mutect2, varscan2
- AGAP4 | c.199G>T p.V67F | Missense Mutation (SNP) | VAF 27/165 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.013); catalogued as COSV71164826; called by mutect2, varscan2
- AGBL2 | c.1371G>T p.L457F | Missense Mutation (SNP) | VAF 126/306 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.114); catalogued as COSV54095417; called by muse, mutect2, varscan2
- AGMO | c.548C>A p.P183H | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61105683, COSV61124079; called by muse, mutect2, varscan2
- AGO4 | c.1289G>T p.R430L | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV64618691; called by muse, mutect2, varscan2
- AGTR1 | c.385G>T p.A129S | Missense Mutation (SNP) | VAF 144/296 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV100837089, COSV62560147; called by muse, mutect2, varscan2
- AHNAK2 | c.7373C>T p.A2458V | Missense Mutation (SNP) | VAF 129/297 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.067); catalogued as rs553916130, COSV60930524; called by muse, mutect2, varscan2
- AHRR | c.28G>T p.A10S | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57093476; called by muse, mutect2, varscan2
- AK5 | c.263C>A p.S88* (on ENST00000354567 / NM_174858.3; = p.S62* on NM_012093.4) | Nonsense Mutation (SNP) | VAF 24/97 reads (25%) | catalogued as COSV58357057; called by muse, mutect2, varscan2
- ALOX12B | c.1420C>A p.L474I | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.062); catalogued as COSV59876428; called by muse, mutect2, varscan2
- ALPI | c.1354G>T p.G452* | Nonsense Mutation (SNP) | VAF 9/27 reads (33%) | catalogued as COSV55016166; called by muse, mutect2, varscan2
- ALX1 | c.319G>T p.V107L | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.094); catalogued as rs750676414, COSV57494152; called by muse, varscan2
- ALX1 | c.383C>G p.S128C | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV100374404, COSV57494158; called by muse, varscan2
- AMER3 | c.933C>A p.D311E | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.119); catalogued as COSV58470042; called by muse, mutect2, varscan2
- AMPD1 | c.1407G>T p.W469C | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100815085, COSV62418974; called by muse, mutect2, varscan2
- AMPH | c.2028C>A p.Y676* | Nonsense Mutation (SNP) | VAF 34/129 reads (26%) | catalogued as COSV57756983; called by muse, mutect2, varscan2
- ANKMY1 | c.444G>T p.Q148H | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.359); catalogued as COSV56040867; called by muse, mutect2, varscan2
- ANKRD13A | c.262G>T p.E88* | Nonsense Mutation (SNP) | VAF 57/99 reads (58%) | catalogued as COSV55678368; called by muse, mutect2, varscan2
- ANKRD17 | c.1918G>C p.A640P | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58227763; called by muse, mutect2, varscan2
- ANKRD50 | c.1903G>C p.V635L | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.137); catalogued as COSV72386313; called by muse, mutect2, varscan2
- ANKS1B | c.2848G>A p.D950N (on ENST00000547776 / NM_152788.4; = p.D176N on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/13 reads (85%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as rs745710683, COSV59117887; called by muse, mutect2, varscan2
- ANO8 | c.2308C>A p.L770M | Missense Mutation (SNP) | VAF 50/101 reads (50%) | SIFT tolerated (0.72); PolyPhen benign (0.132); catalogued as COSV50198921; called by muse, mutect2, varscan2
- ANXA9 | c.541G>T p.A181S | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.391); catalogued as COSV64485596; called by muse, mutect2, varscan2
- AOC2 | c.367A>G p.I123V | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs1406946179, COSV53200341; called by muse, mutect2, varscan2
- AOC3 | c.1857C>A p.S619R | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV53828822; called by muse, mutect2, varscan2
- AOX1 | c.2924A>T p.Q975L | Missense Mutation (SNP) | VAF 35/170 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV65983947; called by muse, mutect2, varscan2
- AP4M1 | c.533G>C p.R178P | Missense Mutation (SNP) | VAF 55/231 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV57998885; called by muse, mutect2, varscan2
- APBB1IP | c.1123A>T p.K375* | Nonsense Mutation (SNP) | VAF 18/88 reads (20%) | catalogued as COSV66136280; called by muse, mutect2, varscan2
- APLNR | c.520G>T p.E174* | Nonsense Mutation (SNP) | VAF 21/65 reads (32%) | catalogued as COSV57243140, COSV57244060; called by muse, mutect2, varscan2
- APOBR | c.919G>A p.G307R | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs751030621, COSV60494044; called by muse, mutect2, varscan2
- APOBR | c.920G>T p.G307V | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV60488494; called by muse, mutect2, varscan2
- APOC3 | c.177C>T p.A59= | Splice Region (SNP) | VAF 6/50 reads (12%) | catalogued as COSV52636799; called by muse, mutect2
- APPBP2 | c.401G>C p.G134A | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.952); catalogued as COSV50029432; called by muse, mutect2, varscan2
- APPL2 | c.1432G>C p.E478Q | Missense Mutation (SNP) | VAF 41/67 reads (61%) | SIFT tolerated (0.25); PolyPhen benign (0.329); catalogued as COSV51593758; called by muse, mutect2, varscan2
- ARC | c.260G>T p.W87L | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.93); catalogued as COSV63079790; called by muse, mutect2
- ARFIP2 | c.494G>T p.G165V | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54448188; called by muse, mutect2, varscan2
- ARHGAP19 | c.242G>T p.G81V | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100363344; called by muse, varscan2
- ARHGAP19 | c.92C>T p.S31F | Missense Mutation (SNP) | VAF 58/132 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.444); catalogued as COSV57396032, COSV57396164; called by muse, varscan2
- ARHGAP5 | c.797G>T p.R266I | Missense Mutation (SNP) | VAF 80/357 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.885); catalogued as COSV61539261; called by muse, mutect2, varscan2
- ARHGEF1 | c.325-2A>C p.X109_splice | Splice Site (SNP) | VAF 54/346 reads (16%) | catalogued as COSV61529628; called by muse, mutect2, varscan2
- ARHGEF11 | c.1372G>T p.G458* | Nonsense Mutation (SNP) | VAF 27/70 reads (39%) | catalogued as COSV63815585; called by muse, mutect2, varscan2
- ARHGEF12 | c.4440G>A p.W1480* | Nonsense Mutation (SNP) | VAF 26/90 reads (29%) | catalogued as COSV63104763; called by muse, mutect2, varscan2
- ARHGEF28 | c.1329G>T p.Q443H | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as COSV55270219; called by muse, mutect2, varscan2
- ARMCX5 | c.555G>T p.W185C | Missense Mutation (SNP) | VAF 88/142 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as COSV55767623; called by muse, mutect2, varscan2
- ARSI | c.1243G>C p.V415L | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.426); catalogued as COSV60816932, COSV60818487; called by muse, mutect2, varscan2
- ART5 | c.520G>T p.D174Y | Missense Mutation (SNP) | VAF 45/95 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs143088148, COSV63365438; called by muse, mutect2, varscan2
- ASCL4 | c.394C>T p.Q132* | Nonsense Mutation (SNP) | VAF 8/12 reads (67%) | catalogued as rs1471916661, COSV60817362; called by muse, mutect2, varscan2
- ASPRV1 | c.1029C>A p.H343Q | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.205); catalogued as COSV57229190; called by muse, mutect2, varscan2
- ASTN2 | c.630G>T p.M210I | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); catalogued as COSV57817272; called by muse, mutect2, varscan2
- ASXL3 | c.1047G>T p.W349C | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV52463564, COSV52479436; called by muse, mutect2, varscan2
- ATAD2 | c.67G>T p.D23Y | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.455); catalogued as COSV54886627; called by muse, mutect2, varscan2
- ATG2B | c.4085A>G p.Y1362C | Missense Mutation (SNP) | VAF 115/286 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55892086; called by muse, mutect2, varscan2
- ATL2 | c.846del p.K282Nfs*32 | Frame Shift Del (DEL) | VAF 36/102 reads (35%) | catalogued as COSV100184858; called by mutect2, pindel*, varscan2
- ATM | c.4987G>T p.G1663C | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.408); catalogued as COSV53774710; called by muse, mutect2, varscan2
- ATP12A | c.1876A>T p.I626F | Missense Mutation (SNP) | VAF 61/111 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54523246; called by muse, mutect2, varscan2
- ATP13A1 | c.2745G>T p.K915N | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.33); PolyPhen benign (0.062); catalogued as COSV52291176; called by muse, mutect2, varscan2
- ATP6V0D2 | c.522T>G p.D174E | Missense Mutation (SNP) | VAF 46/162 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.174); catalogued as COSV53417845; called by muse, mutect2, varscan2
- ATP7A | c.3082G>T p.G1028C | Missense Mutation (SNP) | VAF 68/100 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58453786; called by muse, mutect2, varscan2
- ATP8A2 | c.1855T>G p.F619V | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54976645; called by muse, mutect2, varscan2
- ATP8B3 | c.3671T>A p.V1224E | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV59548546; called by muse, mutect2, varscan2
- ATRNL1 | c.3185G>C p.C1062S | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV58114930, COSV58115648; called by muse, mutect2, varscan2
- ATXN10 | c.151C>A p.L51M | Missense Mutation (SNP) | VAF 69/123 reads (56%) | SIFT tolerated (0.07); PolyPhen benign (0.138); catalogued as COSV53300669; called by muse, mutect2, varscan2
- B3GNTL1 | c.487G>T p.E163* | Nonsense Mutation (SNP) | VAF 21/75 reads (28%) | catalogued as COSV57953963; called by muse, mutect2, varscan2
- B4GALT3 | c.732G>T p.Q244H | Missense Mutation (SNP) | VAF 65/229 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.155); catalogued as COSV60528052; called by muse, mutect2, varscan2
- BAHD1 | c.825G>A p.W275* | Nonsense Mutation (SNP) | VAF 10/95 reads (11%) | catalogued as COSV69084750; called by muse, mutect2
- BAZ2B | c.472G>T p.G158* | Nonsense Mutation (SNP) | VAF 24/173 reads (14%) | catalogued as COSV58609907, COSV58611039; called by muse, mutect2, varscan2
- BBOX1 | c.1046G>A p.R349Q | Missense Mutation (SNP) | VAF 55/146 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755250948, COSV54193956; called by muse, mutect2, varscan2
- BCKDHB | c.742G>T p.A248S | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV57513393, COSV57518713; called by muse, mutect2, varscan2
- BCLAF1 | c.555G>C p.E185D | Missense Mutation (SNP) | VAF 64/381 reads (17%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as COSV62145681, COSV62145887; called by muse, mutect2, varscan2
- BHMT2 | c.766C>A p.P256T | Missense Mutation (SNP) | VAF 55/113 reads (49%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV54874730; called by muse, mutect2, varscan2
- BICC1 | c.1306G>T p.G436C | Missense Mutation (SNP) | VAF 48/136 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.366); catalogued as rs770876712, COSV54065705, COSV54066935; called by muse, mutect2, varscan2
- BLMH | c.370A>T p.R124* | Nonsense Mutation (SNP) | VAF 44/104 reads (42%) | catalogued as COSV55586929; called by muse, mutect2, varscan2
- BMP3 | c.545A>G p.H182R | Missense Mutation (SNP) | VAF 12/212 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0.025); catalogued as COSV51095480; called by muse, mutect2
- BMPER | c.516G>C p.Q172H | Missense Mutation (SNP) | VAF 74/197 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV51831369; called by muse, mutect2, varscan2
- BMPER | c.782G>A p.C261Y | Missense Mutation (SNP) | VAF 55/147 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1467967116, COSV51831376; called by muse, mutect2, varscan2
- BPIFA1 | c.571C>A p.L191M | Missense Mutation (SNP) | VAF 130/271 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV62823915, COSV62825210; called by muse, mutect2, varscan2
- BRDT | c.574G>C p.V192L | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV62863549, COSV62867622; called by muse, mutect2, varscan2
- BRINP3 | c.1169G>T p.S390I | Missense Mutation (SNP) | VAF 68/210 reads (32%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV66541267; called by muse, mutect2, varscan2
- BTK | c.1471C>G p.H491D | Missense Mutation (SNP) | VAF 68/104 reads (65%) | SIFT tolerated (0.06); PolyPhen benign (0.078); catalogued as COSV58120863, COSV58123719; called by muse, mutect2, varscan2
- BTN1A1 | c.233G>A p.R78K | Missense Mutation (SNP) | VAF 35/53 reads (66%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV55069598; called by muse, mutect2, varscan2
- C10orf71 | c.26C>A p.T9K | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as rs1217263883, COSV60513262; called by muse, varscan2
- C19orf73 | c.24A>T p.Q8H | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as COSV55521528; called by muse, mutect2, varscan2
- C20orf194 | c.3508C>G p.H1170D | Missense Mutation (SNP) | VAF 85/162 reads (52%) | SIFT tolerated (0.21); PolyPhen benign (0.143); catalogued as COSV52702788; called by muse, mutect2, varscan2
- C22orf42 | c.28G>T p.G10C | Missense Mutation (SNP) | VAF 47/103 reads (46%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.984); catalogued as COSV66076686; called by muse, mutect2, varscan2
- C2CD2L | c.1073G>A p.S358N | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.5); PolyPhen benign (0.254); catalogued as COSV60884788; called by muse, mutect2, varscan2
- C2orf16 | c.1470G>C p.R490S | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.234); catalogued as COSV62678315; called by muse, mutect2, varscan2
- C4orf17 | c.149G>T p.C50F | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58513603; called by muse, mutect2, varscan2
- C6 | c.1579C>A p.P527T | Missense Mutation (SNP) | VAF 96/302 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54706710, COSV54718456; called by muse, mutect2
- C6orf89 | c.758C>T p.P253L (on ENST00000373685; = p.P260L on NM_152734.4) | Missense Mutation (SNP) | VAF 113/181 reads (62%) | SIFT tolerated (0.08); PolyPhen benign (0.037); catalogued as COSV62103242; called by muse, mutect2, varscan2
- C8A | c.275G>A p.R92K | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.94); PolyPhen benign (0.009); catalogued as COSV63486435; called by muse, mutect2, varscan2
- C9orf40 | c.464A>T p.Y155F | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.705); catalogued as COSV65228821; called by muse, mutect2, varscan2
- CABP5 | c.63G>T p.R21= | Splice Region (SNP) | VAF 30/66 reads (45%) | catalogued as COSV53154093; called by muse, mutect2, varscan2
- CACNA1B | c.1048C>A p.L350M | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53148655; called by muse, mutect2, varscan2
- CACNA1B | c.5173C>A p.H1725N | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV53148665; called by muse, mutect2, varscan2
- CACNA2D4 | c.1047G>T p.Q349H | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54960140; called by muse, mutect2, varscan2
- CACNG7 | c.421T>A p.S141T | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.553); catalogued as COSV55817330; called by muse, mutect2, varscan2
- CAPN6 | c.1484G>T p.R495M | Missense Mutation (SNP) | VAF 31/42 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV60697204; called by muse, mutect2, varscan2
- CAPZA1 | c.400G>A p.D134N | Missense Mutation (SNP) | VAF 58/241 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0.023); catalogued as COSV54147220; called by muse, mutect2, varscan2
- CAPZA3 | c.897A>G p.I299M | Missense Mutation (SNP) | VAF 273/433 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.276); catalogued as rs1363069603, COSV56858765; called by muse, mutect2, varscan2
- CASP10 | c.1262A>T p.Q421L (on ENST00000272879 / NM_032974.5; = p.Q378L on NM_001230.5) | Missense Mutation (SNP) | VAF 73/195 reads (37%) | SIFT tolerated (0.67); PolyPhen benign (0.005); catalogued as COSV53780595; called by muse, mutect2, varscan2
- CAST | c.178C>T p.H60Y (on ENST00000341926; = p.H143Y on NM_001750.7 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.521); catalogued as COSV57789425; called by muse, mutect2, varscan2
- CBL | c.1190G>T p.G397V | Missense Mutation (SNP) | VAF 40/144 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV50630334; called by muse, mutect2, varscan2
- CBLN3 | c.173G>T p.G58V | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as rs375332763; called by mutect2, varscan2
- CCDC148 | c.1696T>C p.Y566H | Missense Mutation (SNP) | VAF 29/161 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51770517; called by muse, mutect2, varscan2
- CCDC170 | c.1984G>T p.G662C | Missense Mutation (SNP) | VAF 49/131 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53346469; called by muse, mutect2, varscan2
- CCDC57 | c.1420G>T p.E474* | Nonsense Mutation (SNP) | VAF 16/46 reads (35%) | catalogued as COSV58937280; called by muse, mutect2
- CCDC57 | c.1419G>T p.Q473H | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV58937294; called by muse, mutect2
- CCDC70 | c.451G>T p.A151S | Missense Mutation (SNP) | VAF 96/185 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.523); catalogued as COSV54431014; called by muse, mutect2, varscan2
- CCDC70 | c.452C>A p.A151D | Missense Mutation (SNP) | VAF 94/181 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.037); catalogued as COSV54431025; called by muse, mutect2, varscan2
- CCDC74B | c.1105G>C p.A369P | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.931); catalogued as COSV60103711; called by muse, mutect2, varscan2
- CCDC83 | c.1096G>T p.G366C (on ENST00000342404 / NM_001286159.2; = p.G397C on NM_173556.5) | Missense Mutation (SNP) | VAF 52/177 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54704933; called by muse, mutect2, varscan2
- CCN6 | c.240G>T p.K80N | Missense Mutation (SNP) | VAF 60/117 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV57889337; called by muse, mutect2, varscan2
- CD1C | c.755G>T p.G252V | Missense Mutation (SNP) | VAF 47/166 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63807652, COSV63807678; called by muse, mutect2, varscan2
- CD200R1L | c.505G>T p.A169S | Missense Mutation (SNP) | VAF 37/57 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68004933; called by muse, mutect2, varscan2
- CD22 | c.2072G>A p.G691E | Missense Mutation (SNP) | VAF 36/199 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV50068175; called by muse, mutect2, varscan2
- CD248 | c.1073C>A p.A358D | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.025); catalogued as COSV60937809; called by muse, mutect2, varscan2
- CD248 | c.742G>T p.E248* | Nonsense Mutation (SNP) | VAF 14/49 reads (29%) | catalogued as COSV60937820; called by muse, mutect2, varscan2
- CD300LG | c.570C>A p.Y190* | Nonsense Mutation (SNP) | VAF 27/126 reads (21%) | catalogued as COSV53222282, COSV53225811; called by muse, mutect2, varscan2
- CD84 | c.959A>T p.Q320L (on ENST00000311224 / NM_001184879.2; = p.Q303L on NM_003874.4) | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV60870794; called by muse, mutect2, varscan2
- CDC14B | c.1043G>A p.R348K | Missense Mutation (SNP) | VAF 30/151 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55793957; called by muse, mutect2, varscan2
- CDH12 | c.64C>G p.P22A | Missense Mutation (SNP) | VAF 75/322 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.039); catalogued as COSV66405981, COSV66444693; called by muse, varscan2
- CDH18 | c.1009T>A p.Y337N | Missense Mutation (SNP) | VAF 29/141 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV56960726; called by muse, mutect2, varscan2
- CDH2 | c.602G>T p.G201V | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52295468, COSV52295962; called by muse, mutect2, varscan2
- CDH4 | c.391C>A p.H131N | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.023); catalogued as COSV64674496; called by muse, mutect2
- CDH5 | c.1541T>A p.F514Y | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV58519938; called by muse, mutect2, varscan2
- CDK14 | c.1041G>T p.L347= (on ENST00000380050 / NM_001287135.2; = p.L329= on NM_012395.3) | Splice Region (SNP) | VAF 48/200 reads (24%) | catalogued as COSV56052006; called by muse, mutect2, varscan2
- CDNF | c.354G>T p.K118N | Missense Mutation (SNP) | VAF 90/217 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1554763936, COSV65806272; called by muse, mutect2, varscan2
- CDR1 | c.218T>C p.M73T | Missense Mutation (SNP) | VAF 56/97 reads (58%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV65164826; called by muse, mutect2, varscan2
- CENPE | c.5212G>C p.D1738H | Missense Mutation (SNP) | VAF 52/148 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as COSV54390146; called by muse, mutect2, varscan2
- CENPP | c.290-1G>T p.X97_splice | Splice Site (SNP) | VAF 45/179 reads (25%) | catalogued as COSV65041797; called by muse, mutect2, varscan2
- CEP120 | c.901C>T p.H301Y | Missense Mutation (SNP) | VAF 130/227 reads (57%) | SIFT deleterious (0.04); PolyPhen benign (0.321); catalogued as COSV60268544; called by muse, mutect2, varscan2
- CEP350 | c.5885G>T p.G1962V | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV62609674; called by muse, mutect2, varscan2
- CERKL | c.1414C>A p.L472M (on ENST00000339098 / NM_001030311.2; = p.L446M on NM_201548.5) | Missense Mutation (SNP) | VAF 50/109 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59208048, COSV59213627; called by muse, mutect2, varscan2
- CERT1 | c.1248G>T p.E416D (on ENST00000405807 / NM_001130105.1; = p.E288D on NM_005713.3) | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.469); catalogued as COSV54664654; called by muse, mutect2, varscan2
- CFAP43 | c.694G>T p.A232S | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.717); catalogued as COSV53381219; called by muse, mutect2, varscan2
- CFAP46 | c.5995G>A p.V1999I | Missense Mutation (SNP) | VAF 87/197 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.017); catalogued as COSV54159492; called by muse, mutect2, varscan2
- CFAP58 | c.352G>T p.E118* | Nonsense Mutation (SNP) | VAF 22/104 reads (21%) | catalogued as COSV57213608; called by muse, mutect2, varscan2
- CFAP65 | c.4858G>T p.A1620S | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as COSV58566232; called by muse, mutect2
- CHRM2 | c.949G>T p.D317Y | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.195); catalogued as COSV57766199; called by muse, mutect2, varscan2
- CHRM3 | c.128C>A p.S43Y | Missense Mutation (SNP) | VAF 49/186 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as COSV55080229, COSV55103433, COSV55104375; called by muse, mutect2, varscan2
- CHRND | c.896T>A p.L299Q | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51330631; called by muse, mutect2, varscan2
- CKM | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 49/231 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV55535250; called by muse, mutect2, varscan2
- CLCNKA | c.736G>A p.G246R | Missense Mutation (SNP) | VAF 60/193 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV58891727; called by muse, varscan2
- CLEC2D | c.443G>T p.G148V | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV51995834; called by muse, mutect2, varscan2
- CLK3 | c.635G>T p.R212L (on ENST00000395066 / NM_001130028.1; = p.R64L on NM_003992.4) | Missense Mutation (SNP) | VAF 28/168 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs146399462, COSV61414867; called by muse, mutect2, varscan2
- CLRN2 | c.601G>T p.A201S | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.088); catalogued as COSV71825288; called by muse, mutect2, varscan2
- CNGB1 | c.12G>A p.W4* | Nonsense Mutation (SNP) | VAF 27/66 reads (41%) | catalogued as COSV51907056; called by muse, mutect2, varscan2
- CNTLN | c.4081G>T p.E1361* | Nonsense Mutation (SNP) | VAF 53/102 reads (52%) | catalogued as COSV52097248; called by muse, mutect2, varscan2
- CNTN4 | c.491C>A p.S164Y | Missense Mutation (SNP) | VAF 123/233 reads (53%) | SIFT tolerated (0.63); PolyPhen benign (0.311); catalogued as COSV61869503, COSV61881190; called by muse, mutect2, varscan2
- CNTNAP2 | c.2135A>T p.N712I | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV62256974; called by muse, mutect2, varscan2
- CNTNAP2 | c.2136C>A p.N712K | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.214); catalogued as rs187552025, COSV62144713, COSV62177655; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNTNAP5 | c.1150C>A p.P384T | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.651); catalogued as COSV70511970; called by muse, mutect2, varscan2
- COL11A1 | c.4989G>C p.W1663C | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100617932, COSV62197233; called by muse, mutect2, varscan2
- COL11A1 | c.3799G>T p.G1267W | Missense Mutation (SNP) | VAF 42/168 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62197245; called by muse, mutect2, varscan2
- COL11A1 | c.2917G>T p.G973* | Nonsense Mutation (SNP) | VAF 23/92 reads (25%) | catalogued as COSV62184788, COSV62197259; called by muse, mutect2, varscan2
- COL11A1 | c.2614G>T p.V872L | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV62197271; called by muse, mutect2, varscan2
- COL11A1 | c.2567G>T p.G856V | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62197284; called by muse, mutect2, varscan2
- COL15A1 | c.1424A>T p.D475V | Missense Mutation (SNP) | VAF 37/70 reads (53%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.075); catalogued as COSV66649179; called by muse, mutect2, varscan2
- COL25A1 | c.347C>A p.S116* | Nonsense Mutation (SNP) | VAF 30/90 reads (33%) | catalogued as COSV67658651; called by muse, mutect2, varscan2
- COL4A1 | c.4204G>T p.G1402C | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1179536054, COSV65431984; called by muse, mutect2, varscan2
- COL5A1 | c.622G>A p.G208S | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as rs759624894, COSV65674647; called by muse, mutect2, varscan2
- COL6A3 | c.9170C>T p.A3057V | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55109552; called by muse, mutect2, varscan2
- COLEC12 | c.1606G>T p.G536* | Nonsense Mutation (SNP) | VAF 15/40 reads (38%) | catalogued as COSV68373892, COSV68374512; called by muse, mutect2
- COQ4 | c.532G>T p.G178W | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55958014; called by muse, mutect2, varscan2
- CORO2B | c.991G>T p.D331Y | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV55957365; called by muse, mutect2, varscan2
- CORO2B | c.1370C>G p.A457G | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV55957373; called by muse, mutect2, varscan2
- CORO7 | c.877C>T p.Q293* | Nonsense Mutation (SNP) | VAF 10/18 reads (56%) | catalogued as COSV52033931; called by muse, mutect2, varscan2
- CPB1 | c.270C>G p.Y90* | Nonsense Mutation (SNP) | VAF 20/152 reads (13%) | catalogued as COSV51575158, COSV51576981; called by muse, mutect2, varscan2
- CPVL | c.609G>T p.E203D | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55308560; called by muse, mutect2, varscan2
- CPXM1 | c.2059G>T p.V687F | Missense Mutation (SNP) | VAF 38/71 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66046783; called by muse, mutect2, varscan2
- CPXM1 | c.1816G>T p.E606* | Nonsense Mutation (SNP) | VAF 49/81 reads (60%) | catalogued as COSV66046787; called by muse, mutect2, varscan2
- CR1 | c.3699A>T p.R1233S | Missense Mutation (SNP) | VAF 99/293 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.341); catalogued as COSV65463222; called by muse, mutect2, varscan2
- CRB1 | c.2954C>A p.A985E | Missense Mutation (SNP) | VAF 56/196 reads (29%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.516); catalogued as COSV66333773; called by muse, mutect2, varscan2
- CRISP1 | c.360C>G p.Y120* | Nonsense Mutation (SNP) | VAF 74/145 reads (51%) | catalogued as COSV59992791, COSV59995367; called by muse, mutect2, varscan2
- CROCC | c.5419G>C p.E1807Q | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV65004094; called by muse, mutect2, varscan2
- CSF2RA | c.77-2A>T p.X26_splice | Splice Site (SNP) | VAF 21/68 reads (31%) | catalogued as COSV62626780; called by muse, mutect2, varscan2
- CSF3R | c.504G>T p.Q168H | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV58972046; called by muse, mutect2, varscan2
- CSF3R | c.164T>A p.L55Q | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); catalogued as COSV58972068; called by muse, mutect2, varscan2
- CSH2 | c.79G>T p.V27F | Missense Mutation (SNP) | VAF 26/165 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as rs570707903, COSV61080072, COSV61081106; called by mutect2, varscan2
- CSMD2 | c.9166G>A p.G3056R | Missense Mutation (SNP) | VAF 37/151 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV53962542; called by muse, mutect2, varscan2
- CSMD3 | c.7205C>A p.P2402H (on ENST00000297405 / NM_001363185.1; = p.P2298H on NM_052900.3) | Missense Mutation (SNP) | VAF 38/232 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV52139225, COSV52347637; called by muse, mutect2, varscan2
- CSMD3 | c.6643G>T p.V2215L (on ENST00000297405 / NM_001363185.1; = p.V2111L on NM_052900.3) | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as COSV52317631; called by muse, varscan2
- CSRP3 | c.209G>A p.G70E | Missense Mutation (SNP) | VAF 85/185 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56390593; called by muse, mutect2, varscan2
- CST11 | c.228G>T p.Q76H | Missense Mutation (SNP) | VAF 56/98 reads (57%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.557); catalogued as COSV63140264; called by muse, mutect2, varscan2
- CUBN | c.9577G>T p.V3193L | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.238); catalogued as COSV64727139; called by muse, mutect2, varscan2
- CUBN | c.8809C>A p.P2937T | Missense Mutation (SNP) | VAF 33/197 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64727140; called by muse, mutect2, varscan2
- CUL5 | c.1891A>T p.R631W | Missense Mutation (SNP) | VAF 37/187 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67610225; called by muse, mutect2, varscan2
- CUX1 | c.675-2A>G p.X225_splice (on ENST00000292535 / NM_181552.4; = p.X236_splice on NM_001913.5) | Splice Site (SNP) | VAF 24/83 reads (29%) | catalogued as COSV52915749; called by muse, mutect2, varscan2
- CUX2 | c.875C>G p.T292S | Missense Mutation (SNP) | VAF 78/149 reads (52%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV55647951; called by muse, mutect2, varscan2
- CYLC2 | c.313G>T p.V105F | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV66339586; called by muse, mutect2, varscan2
- CYP11B1 | c.327C>A p.H109Q | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV52830281; called by muse, mutect2, varscan2
- CYP19A1 | c.1290T>G p.F430L | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53062373; called by muse, mutect2, varscan2
- CYP3A43 | c.1165C>A p.P389T | Missense Mutation (SNP) | VAF 65/166 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs1226815854, COSV55938024; called by muse, mutect2, varscan2
- CYP4F2 | c.984G>A p.E328= | Splice Region (SNP) | VAF 209/415 reads (50%) | catalogued as COSV50002828; called by muse, mutect2, varscan2
- DBN1 | c.749G>T p.R250L | Missense Mutation (SNP) | VAF 142/294 reads (48%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.924); catalogued as COSV52793161, COSV99445937; called by muse, mutect2, varscan2
- DCAF12L1 | c.461C>G p.A154G | Missense Mutation (SNP) | VAF 35/52 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV64422768; called by muse, mutect2, varscan2
- DCAF6 | c.1612+2T>A p.X538_splice (on ENST00000312263 / NM_001349778.1; = p.X558_splice on NM_018442.3 and 4 other RefSeq transcripts) | Splice Site (SNP) | VAF 15/39 reads (38%) | catalogued as COSV56585207; called by muse, mutect2, varscan2
- DCBLD1 | c.720-2A>T p.X240_splice | Splice Site (SNP) | VAF 125/220 reads (57%) | catalogued as COSV51646384; called by muse, mutect2, varscan2
- DCDC1 | c.2743C>G p.L915V (on ENST00000597505 / NM_001367979.1; = p.L22V on NM_020869.3) | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV60312794; called by muse, mutect2, varscan2
- DDI1 | c.1123G>A p.G375R | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV56373201; called by muse, mutect2, varscan2
- DDR1 | c.680G>T p.G227V | Missense Mutation (SNP) | VAF 207/289 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1284627527, COSV61325769; called by muse, mutect2, varscan2
- DDX1 | c.1085C>G p.S362C | Missense Mutation (SNP) | VAF 99/239 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV51843428; called by muse, mutect2, varscan2
- DDX11 | c.340G>A p.V114I | Missense Mutation (SNP) | VAF 91/396 reads (23%) | SIFT tolerated (0.72); PolyPhen benign (0.009); catalogued as COSV52510788; called by mutect2, varscan2
- DDX3X | c.1174G>A p.A392T (on ENST00000399959; = p.A393T on NM_001356.5) | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV67864528; called by muse, mutect2, varscan2
- DEFB128 | c.34T>A p.F12I | Missense Mutation (SNP) | VAF 81/172 reads (47%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.831); catalogued as COSV57685921; called by muse, mutect2, varscan2
- DEPP1 | c.305T>C p.V102A | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1387546054, COSV53575130; called by muse, mutect2, varscan2
- DGKB | c.1449C>A p.F483L | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV51818531; called by muse, mutect2, varscan2
- DGKI | c.2175G>C p.R725S | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.829); catalogued as COSV55975291; called by muse, mutect2, varscan2
- DHRS2 | c.465G>T p.Q155H | Missense Mutation (SNP) | VAF 55/376 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as rs770242537, COSV51634294; called by muse, mutect2, varscan2
- DIDO1 | c.3534G>T p.E1178D | Missense Mutation (SNP) | VAF 46/183 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.312); catalogued as COSV56633795; called by muse, mutect2, varscan2
- DISC1 | c.108G>T p.R36S | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as COSV54406562, COSV54418862; called by muse, mutect2, varscan2
- DISP1 | c.973G>T p.V325L | Missense Mutation (SNP) | VAF 94/301 reads (31%) | SIFT tolerated (0.51); PolyPhen benign (0.006); catalogued as COSV52664992; called by muse, mutect2, varscan2
- DLG2 | c.1221G>A p.M407I | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV54684795; called by muse, mutect2, varscan2
- DLGAP2 | c.1382C>A p.A461E | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.492); catalogued as COSV70103890; called by muse, mutect2, varscan2
- DMD | c.6820G>T p.G2274* | Nonsense Mutation (SNP) | VAF 29/69 reads (42%) | catalogued as COSV58952600; called by muse, mutect2, varscan2
- DMRT2 | c.827C>A p.P276H | Missense Mutation (SNP) | VAF 100/166 reads (60%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52403690; called by muse, mutect2, varscan2
- DMXL2 | c.7628G>T p.G2543V | Missense Mutation (SNP) | VAF 76/170 reads (45%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.617); catalogued as COSV51856126; called by muse, mutect2, varscan2
- DNAH1 | c.26A>G p.Y9C | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs556372594, COSV70236210; called by muse, mutect2, varscan2
- DNAH10 | c.7234G>T p.G2412* (on ENST00000409039; = p.G2351* on NM_207437.3) | Nonsense Mutation (SNP) | VAF 32/52 reads (62%) | catalogued as COSV68987648; called by muse, mutect2, varscan2
- DNAH11 | c.2689G>C p.A897P | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV60981098; called by muse, mutect2, varscan2
- DNAH2 | c.1129del p.H377Tfs*8 | Frame Shift Del (DEL) | VAF 49/110 reads (45%) | catalogued as COSV99317939; called by mutect2, pindel, varscan2
- DNAH9 | c.2530G>T p.D844Y | Missense Mutation (SNP) | VAF 51/106 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as rs571270011, COSV52352887, COSV52376688; called by muse, mutect2, varscan2
- DNAH9 | c.2750C>A p.T917N | Missense Mutation (SNP) | VAF 97/170 reads (57%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV52376695; called by muse, mutect2, varscan2
- DNAI1 | c.789G>T p.M263I | Missense Mutation (SNP) | VAF 90/141 reads (64%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV54284718; called by muse, mutect2, varscan2
- DNASE2B | c.178G>T p.G60W | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101042964; called by muse, varscan2
- DNER | c.2119C>T p.R707W | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201404779, COSV59167037; called by muse, mutect2, varscan2
- DNMT3B | c.-6G>T | Splice Region (SNP) | VAF 35/68 reads (51%) | catalogued as COSV99144346; called by muse, mutect2, varscan2
- DNMT3L | c.232-1G>T p.X78_splice | Splice Site (SNP) | VAF 78/124 reads (63%) | catalogued as COSV54266069; called by muse, mutect2, varscan2
- DOCK1 | c.1845G>T p.Q615H | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV54732741, COSV54759915; called by muse, mutect2, varscan2
- DOCK4 | c.2117A>C p.E706A | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV70243143; called by muse, mutect2
- DPF2 | c.777C>G p.S259= | Splice Region (SNP) | VAF 39/191 reads (20%) | catalogued as COSV52891365; called by muse, mutect2, varscan2
- DPYSL4 | c.1390G>A p.G464R | Missense Mutation (SNP) | VAF 29/145 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); catalogued as COSV53845960; called by muse, mutect2, varscan2
- DSCAM | c.5801G>T p.S1934I | Missense Mutation (SNP) | VAF 52/91 reads (57%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.986); catalogued as COSV68024832, COSV68036048; called by muse, mutect2, varscan2
- DSCAM | c.1931C>T p.T644I | Missense Mutation (SNP) | VAF 50/102 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV68036054; called by muse, mutect2, varscan2
- DSCAM | c.1415C>A p.S472Y | Missense Mutation (SNP) | VAF 62/109 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV68036059; called by muse, mutect2, varscan2
- DSCAML1 | c.6175C>A p.P2059T (on ENST00000321322; = p.P1999T on NM_020693.4) | Missense Mutation (SNP) | VAF 2/6 reads (33%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV58386986; called by muse, mutect2
- DSCAML1 | c.593G>T p.R198L (on ENST00000321322; = p.R138L on NM_020693.4) | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV58381903, COSV58402636; called by muse, mutect2, varscan2
- DUOX2 | c.1882A>T p.K628* | Nonsense Mutation (SNP) | VAF 59/249 reads (24%) | catalogued as COSV66534630; called by muse, mutect2, varscan2
- DVL1 | c.1703A>T p.Q568L (on ENST00000378888 / NM_001330311.2; = p.Q543L on NM_004421.3) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.453); catalogued as COSV59565930; called by muse, mutect2
- DYNC1H1 | c.12523G>T p.E4175* | Nonsense Mutation (SNP) | VAF 31/79 reads (39%) | catalogued as COSV64142416; called by muse, mutect2, varscan2
- EBAG9 | c.328A>T p.I110F | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.178); catalogued as COSV61753786; called by muse, mutect2
- EBNA1BP2 | c.661G>T p.A221S | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as COSV52541616; called by muse, mutect2, varscan2
- EDARADD | c.192C>A p.C64* (on ENST00000334232 / NM_145861.4; = p.C54* on NM_080738.4) | Nonsense Mutation (SNP) | VAF 22/112 reads (20%) | catalogued as COSV62065117; called by muse, mutect2, varscan2
- EDRF1 | c.1937G>T p.G646V (on ENST00000356792 / NM_001202438.2; = p.G612V on NM_015608.2) | Missense Mutation (SNP) | VAF 64/185 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.426); catalogued as COSV61766234; called by muse, mutect2, varscan2
- EFCAB3 | c.500G>A p.R167K | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as rs573185315, COSV59504830; called by muse, mutect2, varscan2
- EHD3 | c.776C>A p.S259Y | Missense Mutation (SNP) | VAF 30/156 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV59032707, COSV59032997; called by muse, mutect2, varscan2
- EIF2AK3 | c.1866G>T p.K622N | Missense Mutation (SNP) | VAF 34/221 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57552146; called by muse, mutect2, varscan2
- EIF4G3 | c.4201-1G>C p.X1401_splice | Splice Site (SNP) | VAF 18/78 reads (23%) | catalogued as COSV51694230; called by muse, mutect2
- ENOPH1 | c.437G>T p.G146V | Missense Mutation (SNP) | VAF 43/148 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56732227; called by muse, mutect2, varscan2
- ENPEP | c.128G>T p.C43F | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.135); catalogued as COSV54457447; called by muse, mutect2, varscan2
- ENTPD5 | c.553+1G>C p.X185_splice | Splice Site (SNP) | VAF 49/137 reads (36%) | catalogued as COSV58224043; called by muse, mutect2, varscan2
- EPHA5 | c.1759G>T p.A587S | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.64); PolyPhen benign (0.184); catalogued as COSV56673745, COSV99897433; called by muse, mutect2, varscan2
- EPHA5 | c.1758G>T p.L586F | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.037); catalogued as COSV56673753; called by muse, mutect2, varscan2
- EPHB3 | c.1648del p.A550Pfs*56 | Frame Shift Del (DEL) | VAF 51/107 reads (48%) | catalogued as COSV100383099; called by mutect2, pindel, varscan2
- EPX | c.1190G>T p.R397L | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs201075574, COSV56599234; called by muse, mutect2, varscan2
- ERAS | c.360C>A p.F120L | Missense Mutation (SNP) | VAF 88/123 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as COSV54433005, COSV54433398; called by muse, mutect2, varscan2
- ERBB4 | c.3672C>A p.N1224K | Missense Mutation (SNP) | VAF 51/274 reads (19%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as COSV61522530; called by muse, mutect2, varscan2
- ERBB4 | c.2624A>T p.Y875F | Missense Mutation (SNP) | VAF 38/190 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.441); catalogued as COSV100726506, COSV61522538; called by muse, mutect2, varscan2
- ERRFI1 | c.1282G>T p.A428S | Missense Mutation (SNP) | VAF 35/140 reads (25%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as COSV66311319; called by muse, mutect2, varscan2
- ESRRG | c.730G>C p.A244P | Missense Mutation (SNP) | VAF 34/171 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as COSV63181262; called by muse, mutect2, varscan2
- ETFA | c.734-1G>A p.X245_splice | Splice Site (SNP) | VAF 17/58 reads (29%) | catalogued as COSV51212388; called by muse, mutect2, varscan2
- ETNPPL | c.897C>G p.F299L | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.649); catalogued as COSV56597534; called by muse, mutect2, varscan2
- EVA1C | c.587A>T p.Q196L | Missense Mutation (SNP) | VAF 47/83 reads (57%) | SIFT deleterious (0.05); PolyPhen benign (0.122); catalogued as COSV55826891; called by muse, mutect2, varscan2
- EVC | c.2222A>C p.E741A | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.582); catalogued as COSV53838021; called by muse, mutect2
- EVC2 | c.3910G>A p.A1304T | Missense Mutation (SNP) | VAF 41/133 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as COSV60402558; called by muse, mutect2, varscan2
- EXO5 | c.988C>T p.R330* | Nonsense Mutation (SNP) | VAF 12/60 reads (20%) | catalogued as rs772199418, COSV56416773; called by muse, varscan2
- EXO5 | c.1062G>T p.W354C | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56416783; called by muse, varscan2
- EXTL1 | c.640C>A p.Q214K | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as COSV65338373; called by muse, mutect2, varscan2
- EYA2 | c.509C>A p.P170H | Missense Mutation (SNP) | VAF 75/128 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); catalogued as COSV57950755; called by muse, mutect2, varscan2
- F5 | c.2816C>A p.S939* | Nonsense Mutation (SNP) | VAF 78/242 reads (32%) | catalogued as COSV63120318, COSV63128413; called by muse, mutect2, varscan2
- FAM153B | c.845C>A p.P282Q (on ENST00000253490; = p.P205Q on NM_001265615.1) | Missense Mutation (SNP) | VAF 122/366 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.904); catalogued as COSV53688648; called by muse, mutect2, varscan2
- FAM71A | c.935T>C p.I312T | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs1157854484, COSV54237268; called by muse, mutect2, varscan2
- FAM83B | c.2402G>T p.C801F | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV60926816; called by muse, mutect2, varscan2
- FANCB | c.2289G>T p.L763F | Missense Mutation (SNP) | VAF 41/77 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60761791; called by muse, mutect2, varscan2
- FANCM | c.3301C>G p.Q1101E | Missense Mutation (SNP) | VAF 52/130 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV57506611; called by muse, mutect2, varscan2
- FAT3 | c.11127C>G p.S3709R | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.111); catalogued as COSV53173335; called by muse, mutect2
- FBN2 | c.3724+1G>T p.X1242_splice | Splice Site (SNP) | VAF 20/43 reads (47%) | catalogued as CS1413867, COSV52544859; called by muse, mutect2, varscan2
- FBXL7 | c.278C>A p.P93Q | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.857); catalogued as COSV104395317, COSV61644207, COSV61653207; called by muse, mutect2, varscan2
- FCGR2C | c.635C>T p.T212I | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.912); catalogued as rs777399731, COSV63441613; called by muse, mutect2, varscan2
- FCN3 | c.131C>A p.P44H | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.754); catalogued as COSV54642823, COSV99585274; called by muse, mutect2, varscan2
- FCRLA | c.195G>T p.E65D (on ENST00000367959; = p.E42D on NM_032738.4) | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.053); catalogued as COSV52688413, COSV99376502; called by muse, mutect2, varscan2
- FGD5 | c.3869C>A p.A1290D | Missense Mutation (SNP) | VAF 43/84 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV53252090; called by muse, mutect2, varscan2
- FGF19 | c.452G>T p.R151L | Missense Mutation (SNP) | VAF 41/127 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV53737312; called by muse, mutect2, varscan2
- FGFRL1 | c.949G>T p.G317C | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1461069330, COSV99294580; called by muse, mutect2
- FGFRL1 | c.1045C>T p.R349C | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs768438794, COSV53256371; called by muse, mutect2, varscan2
- FGGY | c.940G>T p.G314W | Missense Mutation (SNP) | VAF 33/147 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58045658; called by muse, mutect2, varscan2
- FIP1L1 | c.215G>T p.G72V | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60999717; called by muse, mutect2, varscan2
- FLNB | c.5467A>T p.S1823C | Missense Mutation (SNP) | VAF 86/156 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV55895418; called by muse, mutect2, varscan2
- FNBP4 | c.2768C>T p.P923L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.019); catalogued as COSV55452130; called by muse, mutect2
- FOXC2 | c.1486T>C p.Y496H | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV57445361; called by muse, mutect2, varscan2
- FOXD4L1 | c.167A>T p.Q56L | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1216785668, COSV52076595; called by muse, mutect2, varscan2
- FOXD4L4 | c.55G>T p.D19Y | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.496); catalogued as rs1277096465; called by mutect2, varscan2
- FOXD4L5 | c.821C>A p.S274* | Nonsense Mutation (SNP) | VAF 11/106 reads (10%) | catalogued as rs1025870625, COSV101073020, COSV101073276; called by muse, mutect2, varscan2
- FRAS1 | c.7464G>T p.K2488N | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.372); catalogued as rs372346225, COSV53648163; called by muse, mutect2, varscan2
- FRRS1L | c.862C>A p.L288I | Missense Mutation (SNP) | VAF 34/180 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.978); catalogued as COSV73746958; called by muse, mutect2, varscan2
- FRS2 | c.43G>T p.D15Y | Missense Mutation (SNP) | VAF 58/104 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54729783; called by muse, mutect2, varscan2
- FSCB | c.2165A>T p.D722V | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as COSV61219492; called by muse, mutect2, varscan2
- FSIP2 | c.20117C>G p.T6706R | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.692); catalogued as rs368822933, COSV58099535; called by muse, mutect2, varscan2
- FYN | c.85C>G p.R29G | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as COSV57621155; called by muse, mutect2, varscan2
- GAB4 | c.1362G>T p.E454D | Missense Mutation (SNP) | VAF 40/73 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV68755232; called by muse, mutect2, varscan2
- GABBR1 | c.2311+1G>T p.X771_splice | Splice Site (SNP) | VAF 160/269 reads (59%) | catalogued as COSV63544519; called by muse, mutect2, varscan2
- GABPB1 | c.754G>T p.V252F | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV55017610; called by muse, mutect2, varscan2
- GABPB2 | c.514A>T p.N172Y | Missense Mutation (SNP) | VAF 61/186 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); catalogued as COSV64461584; called by muse, mutect2, varscan2
- GABRB3 | c.942C>A p.F314L | Missense Mutation (SNP) | VAF 58/146 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); catalogued as CM1411973, COSV100158472, COSV54683816; called by muse, mutect2, varscan2
- GABRG3 | c.270G>T p.M90I | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.314); catalogued as COSV61533459; called by muse, mutect2, varscan2
- GABRP | c.328C>A p.R110S | Missense Mutation (SNP) | VAF 137/251 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.262); catalogued as COSV54665748; called by muse, mutect2, varscan2
- GAL3ST4 | c.1274G>A p.R425H | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs199565529, COSV57586510; called by muse, mutect2, varscan2
- GALNT13 | c.863C>G p.P288R | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs943316798, COSV67239125; called by muse, mutect2, varscan2
- GALNT5 | c.1690G>T p.E564* | Nonsense Mutation (SNP) | VAF 44/130 reads (34%) | catalogued as COSV52041224; called by muse, mutect2, varscan2
- GAPDH | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 108/265 reads (41%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.034); catalogued as COSV57522062; called by muse, mutect2, varscan2
- GATAD2B | c.485G>T p.R162L | Missense Mutation (SNP) | VAF 67/185 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV64086045; called by muse, mutect2, varscan2
- GCN1 | c.4624A>C p.K1542Q | Missense Mutation (SNP) | VAF 47/120 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56114736; called by muse, mutect2, varscan2
- GDA | c.525C>A p.D175E | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV52997583; called by muse, mutect2, varscan2
- GDAP1L1 | c.358C>A p.R120S | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT tolerated (0.22); PolyPhen benign (0.069); catalogued as COSV100697527, COSV61158883; called by muse, mutect2, varscan2
- GDNF | c.491C>T p.S164F | Missense Mutation (SNP) | VAF 88/278 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as rs868074204, COSV58481880, COSV58482288; called by muse, mutect2, varscan2
- GEN1 | c.991-1G>T p.X331_splice | Splice Site (SNP) | VAF 33/70 reads (47%) | catalogued as COSV58058523; called by muse, mutect2, varscan2
- GET3 | c.117G>T p.W39C | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54407635; called by muse, mutect2, varscan2
- GFI1B | c.226G>T p.A76S | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV59747127; called by muse, mutect2, varscan2
- GH2 | c.291+1G>T p.X97_splice | Splice Site (SNP) | VAF 86/359 reads (24%) | catalogued as COSV60427899; called by muse, mutect2, varscan2
- GHRHR | c.465-1G>T p.X155_splice | Splice Site (SNP) | VAF 19/159 reads (12%) | catalogued as COSV58198071; called by muse, mutect2, varscan2
- GIMAP1 | c.155G>T p.R52L | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT tolerated (0.65); PolyPhen benign (0.055); catalogued as rs1270019036, COSV100212326, COSV56189766; called by muse, mutect2, varscan2
- GIMAP8 | c.1657G>C p.G553R | Missense Mutation (SNP) | VAF 29/131 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV56233860; called by muse, mutect2, varscan2
- GIN1 | c.1472C>T p.T491M | Missense Mutation (SNP) | VAF 39/149 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.096); catalogued as rs759917916, COSV67537797; called by muse, mutect2, varscan2
- GLI3 | c.3374G>T p.G1125V | Missense Mutation (SNP) | VAF 30/133 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.044); catalogued as rs748255243, COSV67894907; called by muse, mutect2, varscan2
- GLRX3 | c.747G>T p.M249I | Missense Mutation (SNP) | VAF 48/102 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.586); catalogued as COSV58694484; called by muse, mutect2, varscan2
- GOLIM4 | c.1032G>T p.E344D | Missense Mutation (SNP) | VAF 79/140 reads (56%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.623); catalogued as COSV58332015; called by muse, mutect2, varscan2
- GPNMB | c.1305C>G p.I435M (on ENST00000381990 / NM_001005340.2; = p.I423M on NM_002510.3) | Missense Mutation (SNP) | VAF 84/246 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV51701078; called by muse, varscan2
- GPNMB | c.1367G>T p.R456L (on ENST00000381990 / NM_001005340.2; = p.R444L on NM_002510.3) | Missense Mutation (SNP) | VAF 58/158 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51701094, COSV51701235; called by muse, varscan2
- GPR25 | c.823C>A p.L275M | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.944); catalogued as COSV58499162; called by muse, mutect2, varscan2
- GPR65 | c.977C>A p.S326Y | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV50864296; called by muse, mutect2, varscan2
- GPX8 | c.361G>C p.E121Q | Missense Mutation (SNP) | VAF 50/99 reads (51%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.646); catalogued as COSV57057433; called by muse, mutect2, varscan2
- GREB1 | c.1751A>G p.Q584R | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); catalogued as rs373775125; called by muse, mutect2, varscan2
- GRID1 | c.194A>T p.K65M | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV60052912; called by muse, mutect2, varscan2
- GRID2 | c.311C>A p.S104Y | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV56253969, COSV56265711; called by muse, mutect2, varscan2
- GRID2 | c.3017C>A p.S1006Y | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as COSV56265719; called by muse, mutect2, varscan2
- GRM3 | c.1137C>G p.I379M | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.071); catalogued as rs759058026, COSV64472598, COSV64479666; called by muse, mutect2, varscan2
- GRM7 | c.1124A>T p.K375M | Missense Mutation (SNP) | VAF 69/122 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV63170964; called by muse, mutect2, varscan2
- GRM8 | c.1801G>C p.V601L | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.633); catalogued as COSV58868126; called by muse, mutect2, varscan2
- GSDMD | c.1171G>T p.E391* | Nonsense Mutation (SNP) | VAF 8/47 reads (17%) | catalogued as COSV52797984, COSV52798267; called by muse, mutect2, varscan2
- GTF3C2 | c.1630G>T p.G544W | Missense Mutation (SNP) | VAF 77/356 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99273292; called by muse, mutect2, varscan2
- GTF3C5 | c.65G>A p.R22Q | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV59600709; called by muse, mutect2
- GTSE1 | c.223G>A p.V75I | Missense Mutation (SNP) | VAF 148/278 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV71889506, COSV71889824; called by muse, mutect2, varscan2
- GUCY2C | c.259G>T p.G87C | Missense Mutation (SNP) | VAF 77/221 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.726); catalogued as COSV53795523; called by muse, mutect2, varscan2
- GUCY2D | c.1143C>G p.H381Q | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as COSV54698979; called by muse, mutect2, varscan2
- H2BW1 | c.123G>T p.Q41H | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as COSV54221433; called by muse, mutect2, varscan2
- H3C1 | c.190C>A p.R64S | Missense Mutation (SNP) | VAF 66/97 reads (68%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.261); catalogued as COSV55120578; called by muse, mutect2, varscan2
- H3C6 | c.142G>T p.A48S | Missense Mutation (SNP) | VAF 73/102 reads (72%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.235); catalogued as rs760490205, COSV64519901; called by muse, mutect2, varscan2
- HAP1 | c.748G>A p.D250N | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV57880800; called by muse, mutect2, varscan2
- HAUS5 | c.1803G>T p.Q601H | Missense Mutation (SNP) | VAF 64/152 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52549863; called by muse, mutect2, varscan2
- HDAC9 | c.2689C>A p.P897T | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV67785150; called by muse, mutect2
- HEATR5B | c.5911+1G>T p.X1971_splice | Splice Site (SNP) | VAF 48/97 reads (49%) | catalogued as COSV51859098; called by muse, mutect2, varscan2
- HECTD4 | c.1287G>T p.E429D | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT tolerated (0.76); PolyPhen probably damaging (0.995); catalogued as COSV66399804; called by muse, mutect2, varscan2
- HELZ2 | c.6851A>T p.H2284L (on ENST00000467148 / NM_001037335.2; = p.H1715L on NM_033405.3) | Missense Mutation (SNP) | VAF 123/343 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64443521; called by muse, mutect2, varscan2
- HEMGN | c.1297C>A p.P433T | Missense Mutation (SNP) | VAF 77/390 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.062); catalogued as COSV52328201; called by muse, mutect2, varscan2
- HERC1 | c.12966G>A p.Q4322= | Splice Region (SNP) | VAF 79/368 reads (21%) | catalogued as COSV71250240; called by muse, varscan2
- HIVEP2 | c.5599G>T p.D1867Y | Missense Mutation (SNP) | VAF 153/283 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV50061801; called by muse, mutect2, varscan2
- HLX | c.53C>A p.S18* | Nonsense Mutation (SNP) | VAF 8/25 reads (32%) | catalogued as COSV65045665; called by muse, mutect2, varscan2
- HNRNPA2B1 | c.710G>T p.G237V (on ENST00000354667 / NM_031243.3; = p.G225V on NM_002137.4) | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV61161165; called by muse, mutect2, varscan2
- HNRNPR | c.1685G>A p.R562Q | Missense Mutation (SNP) | VAF 37/193 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV56424280, COSV56424791; called by muse, mutect2, varscan2
- HOXA7 | c.115G>T p.G39C | Missense Mutation (SNP) | VAF 17/161 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs765294385, COSV99636477, COSV99636778; called by muse, mutect2, varscan2
- HOXD12 | c.493G>T p.D165Y | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.897); catalogued as rs758504160, COSV101184225, COSV66832975; called by muse, mutect2, varscan2
- HRH2 | c.835G>C p.A279P | Missense Mutation (SNP) | VAF 51/88 reads (58%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.793); catalogued as COSV51576332; called by muse, mutect2, varscan2
- HRNR | c.959C>A p.S320Y | Missense Mutation (SNP) | VAF 64/163 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as COSV64262891, COSV64262902; called by muse, mutect2, varscan2
- HSPB11 | c.174G>T p.R58S | Missense Mutation (SNP) | VAF 56/172 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV52041927; called by muse, mutect2, varscan2
- HTR1A | c.1190C>A p.P397H | Missense Mutation (SNP) | VAF 144/331 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60502913; called by muse, mutect2, varscan2
- HTR1A | c.1189C>A p.P397T | Missense Mutation (SNP) | VAF 142/331 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60502922; called by muse, mutect2, varscan2
- HTR3A | c.776T>C p.M259T | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.232); catalogued as rs776946829, COSV55471536; called by muse, mutect2, varscan2
- HTR3A | c.1208G>T p.S403I | Missense Mutation (SNP) | VAF 40/149 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.111); catalogued as COSV55471559; called by muse, mutect2, varscan2
- HUNK | c.806G>T p.S269I | Missense Mutation (SNP) | VAF 128/207 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV54234373; called by muse, mutect2, varscan2
- IDH3B | c.592G>T p.A198S | Missense Mutation (SNP) | VAF 72/121 reads (60%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV61391708; called by muse, mutect2, varscan2
- IFT172 | c.1285G>T p.G429C | Missense Mutation (SNP) | VAF 68/359 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.746); catalogued as COSV53139303; called by muse, mutect2, varscan2
- IFT52 | c.565G>C p.V189L | Missense Mutation (SNP) | VAF 49/92 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.254); catalogued as rs1419410200, COSV65976184; called by muse, mutect2, varscan2
- IGF2R | c.4849G>T p.E1617* | Nonsense Mutation (SNP) | VAF 36/75 reads (48%) | catalogued as COSV63632676; called by muse, mutect2, varscan2
- IL18RAP | c.530G>A p.S177N | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); catalogued as rs1453932697, COSV51829348; called by muse, mutect2, varscan2
- IL7R | c.453T>A p.N151K | Missense Mutation (SNP) | VAF 48/148 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.195); catalogued as COSV57413355; called by muse, mutect2, varscan2
- IMPG1 | c.1274C>A p.A425E | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as rs1562365582, COSV64061833; called by muse, mutect2, varscan2
- INA | c.9C>G p.F3L | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV63976155, COSV63976585; called by muse, mutect2, varscan2
- INHBA | c.1213G>A p.D405N | Missense Mutation (SNP) | VAF 51/138 reads (37%) | SIFT tolerated (0.59); PolyPhen benign (0.202); catalogued as COSV54225241; called by muse, mutect2, varscan2
- INPP4B | c.2355G>T p.M785I | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV53745320; called by muse, mutect2, varscan2
- INTS1 | c.2120A>G p.N707S | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.168); catalogued as COSV67179721; called by muse, mutect2, varscan2
- INTS1 | c.683A>T p.K228M | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV67179726; called by mutect2, varscan2
- INTS1 | c.463A>C p.K155Q | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV67179731; called by muse, mutect2, varscan2
- IQCA1 | c.1824C>A p.Y608* | Nonsense Mutation (SNP) | VAF 93/182 reads (51%) | catalogued as COSV54512722; called by muse, mutect2, varscan2
- IQSEC3 | c.2140C>A p.R714S (on ENST00000538872 / NM_001170738.2; = p.R411S on NM_015232.1) | Missense Mutation (SNP) | VAF 39/207 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.205); catalogued as COSV100407647; called by muse, mutect2, varscan2
- IRF6 | c.509-1G>T p.X170_splice | Splice Site (SNP) | VAF 22/72 reads (31%) | catalogued as COSV65419596; called by muse, mutect2, varscan2
- IRX5 | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 74/125 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV58060003; called by muse, mutect2, varscan2
- ISLR2 | c.133G>T p.V45L | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); catalogued as COSV62303780; called by muse, mutect2, varscan2
- ITGA1 | c.3180+2T>C p.X1060_splice | Splice Site (SNP) | VAF 40/76 reads (53%) | catalogued as COSV50898165; called by muse, mutect2, varscan2
- ITGAD | c.100G>T p.G34C | Missense Mutation (SNP) | VAF 31/158 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101210590, COSV66757244; called by muse, mutect2, varscan2
- ITGAV | c.1709C>T p.A570V | Missense Mutation (SNP) | VAF 105/259 reads (41%) | SIFT tolerated (0.8); PolyPhen benign (0.395); catalogued as rs199670325; called by muse, mutect2, varscan2
- ITGB3 | c.1459C>T p.R487C | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.259); catalogued as rs369140365, COSV71383511, COSV71384366; called by muse, mutect2, varscan2
- ITIH4 | c.1582G>A p.E528K | Missense Mutation (SNP) | VAF 111/191 reads (58%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV56578707; called by muse, mutect2, varscan2
- ITIH5 | c.2197G>T p.G733C | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53673789; called by muse, mutect2, varscan2
- ITPR2 | c.4012G>T p.G1338W | Missense Mutation (SNP) | VAF 305/546 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1463093343, COSV67276086; called by muse, mutect2, varscan2
- ITPR2 | c.2623G>T p.G875* | Nonsense Mutation (SNP) | VAF 38/205 reads (19%) | catalogued as COSV67276087; called by muse, mutect2, varscan2
- KANK4 | c.2632G>A p.V878I | Missense Mutation (SNP) | VAF 35/141 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.678); catalogued as rs747158846, COSV58092859, COSV58094112; called by muse, mutect2, varscan2
- KANK4 | c.2032G>A p.E678K | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1303936679, COSV62989328; called by muse, mutect2, varscan2
- KAT6B | c.436C>A p.P146T | Missense Mutation (SNP) | VAF 68/138 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.575); catalogued as COSV54754602; called by muse, mutect2, varscan2
- KCNA2 | c.313C>A p.P105T | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV60370865, COSV60371507; called by muse, mutect2, varscan2
- KCNA5 | c.758C>G p.A253G | Missense Mutation (SNP) | VAF 153/406 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); catalogued as COSV52908707, COSV52908911; called by muse, mutect2, varscan2
- KCNAB2 | c.184G>A p.G62S | Missense Mutation (SNP) | VAF 29/144 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.045); catalogued as COSV51235853, COSV51239278; called by muse, mutect2, varscan2
- KCNAB2 | c.712G>T p.V238L | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.042); catalogued as COSV51239293; called by muse, mutect2, varscan2
- KCNB2 | c.22G>T p.G8C | Missense Mutation (SNP) | VAF 36/202 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.942); catalogued as COSV73052990; called by muse, mutect2, varscan2
- KCND2 | c.481G>C p.A161P | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV58574829, COSV58603668; called by muse, mutect2, varscan2
- KCNH1 | c.1996T>A p.Y666N (on ENST00000271751 / NM_172362.3; = p.Y639N on NM_002238.4) | Missense Mutation (SNP) | VAF 51/156 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55103657; called by muse, mutect2, varscan2
- KCNH6 | c.823C>A p.P275T | Missense Mutation (SNP) | VAF 44/152 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV59007570; called by muse, mutect2, varscan2
- KCNH6 | c.824C>A p.P275H | Missense Mutation (SNP) | VAF 43/151 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59007581; called by muse, mutect2, varscan2
- KCNJ2 | c.718G>A p.G240R | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54663911; called by muse, mutect2, varscan2
- KCNJ3 | c.1162T>A p.C388S | Missense Mutation (SNP) | VAF 43/226 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as COSV54544613; called by muse, mutect2, varscan2
- KCNK10 | c.1060A>T p.T354S | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.913); catalogued as COSV56652496; called by muse, mutect2, varscan2
- KCNMA1 | c.722G>A p.W241* | Nonsense Mutation (SNP) | VAF 23/76 reads (30%) | catalogued as COSV54287346; called by muse, mutect2, varscan2
- KCNQ3 | c.1152G>T p.R384S | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV66481848; called by muse, mutect2, varscan2
- KCNU1 | c.2839G>T p.V947L | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs1309583698, COSV67759786; called by muse, mutect2, varscan2
- KCTD16 | c.1249C>T p.P417S | Missense Mutation (SNP) | VAF 62/134 reads (46%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs376520312; called by muse, mutect2, varscan2
- KCTD8 | c.257G>T p.R86L | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated, low confidence (0.3); PolyPhen possibly damaging (0.506); catalogued as COSV63596438, COSV99077649; called by muse, mutect2, varscan2
- KDM4C | c.1936G>T p.A646S | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.788); catalogued as COSV67192992; called by muse, mutect2, varscan2
- KDM7A | c.769G>C p.D257H | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50096072; called by muse, mutect2, varscan2
- KIAA0100 | c.3691G>T p.A1231S | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV66496321; called by muse, mutect2, varscan2
- KIAA1210 | c.1691A>T p.Y564F | Missense Mutation (SNP) | VAF 117/179 reads (65%) | SIFT tolerated (0.7); PolyPhen benign (0.01); catalogued as COSV68180215; called by muse, varscan2
- KIAA1549L | c.3833C>A p.T1278N (on ENST00000321505; = p.T1575N on NM_012194.3) | Missense Mutation (SNP) | VAF 49/135 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV55781003; called by muse, mutect2, varscan2
- KIAA2013 | c.1426G>T p.V476L | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.8); catalogued as COSV64860904, COSV64861228; called by muse, mutect2, varscan2
- KIF11 | c.1129G>C p.E377Q | Missense Mutation (SNP) | VAF 53/122 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53274091; called by muse, mutect2, varscan2
- KIF17 | c.308G>T p.G103V | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56122420; called by muse, mutect2, varscan2
- KIF21B | c.4261A>T p.S1421C (on ENST00000422435 / NM_001252100.2; = p.S1408C on NM_017596.4) | Missense Mutation (SNP) | VAF 80/236 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV59766571; called by muse, mutect2, varscan2
- KIF27 | c.1985G>T p.R662I | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV52831191; called by muse, mutect2, varscan2
- KIF2C | c.2116C>A p.L706M | Missense Mutation (SNP) | VAF 33/171 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as COSV64765666; called by muse, mutect2, varscan2
- KIR2DL4 | c.178G>T p.V60L (on ENST00000396284; = p.V21L on NM_001080770.2) | Missense Mutation (SNP) | VAF 120/308 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.281); catalogued as rs1404928322, COSV60881037; called by muse, mutect2, varscan2
- KIR2DL4 | c.908G>T p.R303L (on ENST00000396284; = p.R264L on NM_001080772.2) | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as rs1292295087; called by muse, mutect2
- KIRREL2 | c.1163C>A p.A388D | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated (0.08); PolyPhen benign (0.055); catalogued as COSV52880089; called by muse, mutect2, varscan2
- KLK3 | c.445G>T p.G149W | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58102963; called by muse, mutect2, varscan2
- KMT2B | c.3140G>A p.R1047Q | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as rs774265693, COSV55869560; called by muse, mutect2, varscan2
- KPRP | c.286G>T p.G96C | Missense Mutation (SNP) | VAF 159/444 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.013); catalogued as COSV64223007; called by muse, mutect2, varscan2
- KRT75 | c.39C>A p.S13R | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT tolerated (0.08); PolyPhen benign (0.36); catalogued as COSV52875276; called by muse, mutect2, varscan2
- KRTAP13-1 | c.257C>A p.S86Y | Missense Mutation (SNP) | VAF 58/104 reads (56%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.969); catalogued as COSV62664367; called by muse, mutect2, varscan2
- KRTAP5-10 | c.393G>T p.K131N | Missense Mutation (SNP) | VAF 41/187 reads (22%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV100924168; called by muse, mutect2, varscan2
- KRTAP9-8 | c.290C>A p.A97E | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT tolerated (1); PolyPhen possibly damaging (0.886); catalogued as COSV54201001; called by muse, mutect2, varscan2
- L1CAM | c.2624C>A p.A875D | Missense Mutation (SNP) | VAF 93/141 reads (66%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as COSV62830134; called by muse, mutect2, varscan2
- LAMA3 | c.4156G>T p.G1386W | Missense Mutation (SNP) | VAF 40/374 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100557686; called by muse, mutect2, varscan2
- LARS2 | c.367A>G p.I123V | Missense Mutation (SNP) | VAF 105/172 reads (61%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV55532084; called by muse, mutect2, varscan2
- LEFTY2 | c.859G>T p.G287C | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64747694; called by muse, mutect2
- LGALS2 | c.233C>A p.P78Q | Missense Mutation (SNP) | VAF 109/209 reads (52%) | SIFT tolerated (0.46); PolyPhen benign (0.07); catalogued as COSV50757985; called by muse, mutect2, varscan2
- LGALS9 | c.209G>T p.G70V | Missense Mutation (SNP) | VAF 40/182 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56351330; called by muse, mutect2, varscan2
- LGI4 | c.769T>A p.F257I | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV59535113; called by muse, mutect2, varscan2
- LILRA4 | c.953G>T p.G318V | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as rs773279262, COSV52494773, COSV99393171; called by muse, mutect2, varscan2
- LILRA5 | c.76C>A p.L26M | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56645233; called by muse, mutect2, varscan2
- LILRB4 | c.1309C>A p.P437T (on ENST00000391733 / NM_001278428.3; = p.P436T on NM_001278426.3) | Missense Mutation (SNP) | VAF 56/172 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.046); catalogued as COSV54407531, COSV54408605; called by muse, mutect2, varscan2
- LINGO1 | c.829G>C p.A277P | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.176); catalogued as COSV62438572; called by muse, mutect2, varscan2
- LONRF2 | c.1729G>T p.G577C | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66542422; called by muse, mutect2, varscan2
- LRFN5 | c.343A>T p.T115S | Missense Mutation (SNP) | VAF 49/140 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.012); catalogued as COSV53275094; called by muse, mutect2, varscan2
- LRIG3 | c.2887A>T p.S963C | Missense Mutation (SNP) | VAF 99/175 reads (57%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.319); catalogued as COSV57869818; called by muse, mutect2, varscan2
- LRP1B | c.5356A>G p.M1786V | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs1187165732, COSV67274328; called by muse, mutect2, varscan2
- LRP2 | c.3142G>C p.V1048L | Missense Mutation (SNP) | VAF 74/368 reads (20%) | SIFT tolerated (0.65); PolyPhen benign (0.058); catalogued as COSV55574078; called by muse, mutect2, varscan2
- LRP4 | c.1991A>G p.N664S | Missense Mutation (SNP) | VAF 34/195 reads (17%) | SIFT tolerated (0.7); PolyPhen benign (0.024); catalogued as COSV66138654; called by muse, mutect2, varscan2
- LRRC28 | c.1090G>C p.D364H | Missense Mutation (SNP) | VAF 233/589 reads (40%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as rs1403509799, COSV57342077; called by muse, mutect2, varscan2
- LRRC37B | c.695T>C p.L232P | Missense Mutation (SNP) | VAF 48/182 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.04); catalogued as rs1371811625, COSV58954956; called by muse, mutect2, varscan2
- LRRC49 | c.888G>T p.M296I | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV53015560; called by muse, mutect2, varscan2
- LRRC4C | c.664G>T p.D222Y | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as COSV53437898, COSV99538561; called by muse, varscan2
- LRRC7 | c.4288G>T p.E1430* (on ENST00000651989 / NM_001370785.2; = p.E1350* on NM_001330635.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 23/93 reads (25%) | catalogued as COSV50626933; called by muse, mutect2, varscan2
- LRRC8B | c.1750A>G p.M584V | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV58377161; called by muse, mutect2, varscan2
- LRRK2 | c.6280+1G>T p.X2094_splice | Splice Site (SNP) | VAF 30/70 reads (43%) | catalogued as COSV54170337; called by muse, mutect2, varscan2
- LTBP1 | c.2699G>T p.C900F (on ENST00000404816 / NM_206943.4; = p.C574F on NM_000627.4) | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63197899; called by muse, mutect2, varscan2
- LY6H | c.68C>A p.A23D | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.264); catalogued as COSV61371523; called by muse, mutect2, varscan2
- LY75 | c.917G>T p.R306M | Missense Mutation (SNP) | VAF 81/235 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV55113044; called by muse, mutect2, varscan2
- MACF1 | c.20055G>T p.Q6685H (on ENST00000372915; = p.Q4730H on NM_012090.5) | Missense Mutation (SNP) | VAF 18/81 reads (22%) | catalogued as COSV57143930; called by muse, mutect2, varscan2
- MAGEA4 | c.76G>T p.V26L | Missense Mutation (SNP) | VAF 44/57 reads (77%) | SIFT tolerated (0.22); PolyPhen benign (0.389); catalogued as COSV52343153; called by muse, mutect2, varscan2
- MAGEC2 | c.268G>T p.G90C | Missense Mutation (SNP) | VAF 35/54 reads (65%) | SIFT tolerated (0.07); PolyPhen benign (0.393); catalogued as COSV56001479; called by muse, mutect2, varscan2
- MAGI2 | c.2297G>T p.R766L | Missense Mutation (SNP) | VAF 31/150 reads (21%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.968); catalogued as rs746033133, COSV62676179, COSV62701916; called by muse, mutect2, varscan2
- MAP3K9 | c.1303G>T p.D435Y | Missense Mutation (SNP) | VAF 41/191 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV67119895, COSV67121431, COSV67122863; called by muse, mutect2, varscan2
- MAP4K5 | c.1507G>A p.D503N | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT tolerated (1); PolyPhen probably damaging (0.998); catalogued as COSV50161108; called by muse, mutect2, varscan2
- MARCHF11 | c.1025G>C p.R342T | Missense Mutation (SNP) | VAF 26/158 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.082); catalogued as COSV60133073, COSV60134974; called by muse, mutect2, varscan2
- MCTP2 | c.1522G>T p.V508F | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.553); catalogued as COSV59150322; called by muse, mutect2, varscan2
- MDH1B | c.23-1G>T p.X8_splice | Splice Site (SNP) | VAF 88/197 reads (45%) | catalogued as COSV52700203; called by muse, mutect2, varscan2
- METTL14 | c.85G>T p.D29Y | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs200462174; called by muse, mutect2, varscan2
- MFSD1 | c.43G>C p.G15R | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV51843328; called by muse, mutect2, varscan2
- MFSD2A | c.913G>T p.G305C (on ENST00000372809 / NM_001136493.3; = p.G292C on NM_032793.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 49/177 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV65686178, COSV65686487; called by muse, mutect2, varscan2
- MGST1 | c.432G>T p.M144I | Missense Mutation (SNP) | VAF 119/268 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV50567527; called by muse, mutect2, varscan2
- MMP16 | c.1587T>G p.F529L | Missense Mutation (SNP) | VAF 53/126 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.248); catalogued as COSV54189020; called by muse, mutect2, varscan2
- MMP20 | c.848C>A p.P283H | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as COSV52774778; called by muse, mutect2, varscan2
- MMP9 | c.2121C>A p.D707E | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as COSV63434474; called by muse, mutect2, varscan2
- MNDA | c.1126A>T p.T376S | Missense Mutation (SNP) | VAF 61/184 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.629); catalogued as COSV63742096; called by muse, mutect2, varscan2
- MOG | c.371G>C p.G124A | Missense Mutation (SNP) | VAF 83/105 reads (79%) | SIFT tolerated (0.16); PolyPhen probably damaging (1); catalogued as COSV65321779; called by muse, mutect2, varscan2
- MOG | c.439C>A p.P147T | Missense Mutation (SNP) | VAF 191/282 reads (68%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV65321782; called by muse, mutect2, varscan2
- MOV10L1 | c.560G>C p.C187S | Missense Mutation (SNP) | VAF 69/138 reads (50%) | SIFT tolerated (0.47); PolyPhen benign (0.052); catalogued as COSV53179121; called by muse, mutect2, varscan2
- MPEG1 | c.1089C>A p.N363K | Missense Mutation (SNP) | VAF 72/159 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57095007; called by muse, mutect2, varscan2
- MPL | c.757T>C p.W253R | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as rs745790969, COSV65247242; called by muse, mutect2, varscan2
- MPPED2 | c.496G>T p.E166* | Nonsense Mutation (SNP) | VAF 42/120 reads (35%) | catalogued as COSV63900790, COSV63901242; called by muse, mutect2, varscan2
- MS4A3 | c.124G>T p.D42Y | Missense Mutation (SNP) | VAF 34/182 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.118); catalogued as COSV53937891; called by muse, mutect2, varscan2
- MSN | c.519G>T p.Q173H | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as COSV64305483; called by muse, mutect2, varscan2
- MTMR2 | c.298G>T p.A100S | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.046); catalogued as COSV60582062; called by muse, mutect2, varscan2
- MTRR | c.84G>T p.M28I (on ENST00000264668; = p.M1? on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/133 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.3); catalogued as COSV52941985, COSV52942816; called by muse, mutect2, varscan2
- MTUS1 | c.2772G>T p.Q924H (on ENST00000262102 / NM_001363061.1; = p.Q90H on NM_020749.4) | Missense Mutation (SNP) | VAF 48/144 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as COSV50589708; called by muse, mutect2, varscan2
- MUC16 | c.38630C>A p.S12877Y | Missense Mutation (SNP) | VAF 89/161 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV67493741; called by muse, mutect2, varscan2
- MUC16 | c.35942C>A p.T11981K | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV67493749; called by muse, mutect2, varscan2
- MUC16 | c.35359C>A p.P11787T | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.722); catalogued as COSV67446836, COSV67493766; called by muse, mutect2, varscan2
- MUC16 | c.15257G>T p.R5086L | Missense Mutation (SNP) | VAF 91/195 reads (47%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.106); catalogued as COSV67442388, COSV67493775; called by muse, mutect2, varscan2
- MUC16 | c.14542G>C p.V4848L | Missense Mutation (SNP) | VAF 41/86 reads (48%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.533); catalogued as COSV67493784; called by muse, mutect2, varscan2
- MUC16 | c.10757C>A p.T3586K | Missense Mutation (SNP) | VAF 71/119 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.028); catalogued as COSV67493791; called by muse, mutect2, varscan2
- MUC17 | c.1960G>C p.V654L | Missense Mutation (SNP) | VAF 109/372 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV60303268; called by muse, mutect2, varscan2
- MUC17 | c.2317G>A p.D773N | Missense Mutation (SNP) | VAF 96/331 reads (29%) | SIFT tolerated (0.6); PolyPhen benign (0.134); catalogued as COSV60303278; called by muse, mutect2, varscan2
- MXRA5 | c.5703G>T p.R1901S | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); catalogued as COSV54250530; called by muse, mutect2, varscan2
- MXRA5 | c.2983G>T p.E995* | Nonsense Mutation (SNP) | VAF 41/83 reads (49%) | catalogued as COSV54250552; called by muse, mutect2, varscan2
- MYADM | c.401G>A p.R134Q | Missense Mutation (SNP) | VAF 35/157 reads (22%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.916); catalogued as rs763442113, COSV61240768, COSV61240936; called by muse, mutect2, varscan2
- MYBPC1 | c.1598A>T p.N533I (on ENST00000550270 / NM_206820.2; = p.N558I on NM_002465.4) | Missense Mutation (SNP) | VAF 43/86 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62257598; called by muse, mutect2, varscan2
- MYBPC3 | c.2608C>A p.P870T | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV57033566; called by muse, mutect2, varscan2
- MYCBP2 | c.1643C>G p.S548* (on ENST00000357337; = p.S586* on NM_015057.5) | Nonsense Mutation (SNP) | VAF 80/157 reads (51%) | catalogued as COSV100631988, COSV62039062; called by muse, mutect2, varscan2
- MYH1 | c.3131A>T p.Q1044L | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.15); catalogued as COSV56857002; called by muse, mutect2, varscan2
- MYH1 | c.551G>A p.G184E | Missense Mutation (SNP) | VAF 51/103 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56857009; called by muse, mutect2, varscan2
- MYH3 | c.3691G>T p.D1231Y | Missense Mutation (SNP) | VAF 76/149 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56869964; called by muse, mutect2, varscan2
- MYH7B | c.3775C>A p.Q1259K | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV52684496; called by muse, mutect2, varscan2
- MYL2 | c.402G>C p.E134D | Missense Mutation (SNP) | VAF 70/147 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.245); catalogued as rs727504408, COSV57405983, COSV57406204, COSV57408090; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO18A | c.3869G>C p.R1290P | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV62871374, COSV62873198; called by muse, mutect2, varscan2
- MYO1C | c.1103C>T p.P368L (on ENST00000648651 / NM_001080779.2; = p.P333L on NM_033375.5) | Missense Mutation (SNP) | VAF 54/102 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs139543770, COSV63000242; called by muse, mutect2, varscan2
- MYO3A | c.2877G>T p.Q959H | Missense Mutation (SNP) | VAF 58/155 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.076); catalogued as rs1227394916, COSV56349376; called by muse, varscan2
- MYO7B | c.5123A>T p.D1708V | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67352030; called by mutect2, varscan2
- MYO9A | c.858G>T p.K286N | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61857827; called by muse, mutect2, varscan2
- MYPN | c.1204C>A p.Q402K | Missense Mutation (SNP) | VAF 29/143 reads (20%) | SIFT tolerated (0.89); PolyPhen benign (0.01); catalogued as COSV100590642; called by muse, mutect2, varscan2
- MYT1L | c.2296G>T p.D766Y | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV67732530; called by muse, mutect2
- N4BP2 | c.2042C>A p.P681Q | Missense Mutation (SNP) | VAF 41/140 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.154); catalogued as COSV54706882; called by muse, mutect2, varscan2
- NAALAD2 | c.1131C>A p.D377E | Missense Mutation (SNP) | VAF 65/275 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58966095, COSV58966942; called by muse, mutect2, varscan2
- NADSYN1 | c.620G>C p.R207P | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV59815065; called by muse, mutect2, varscan2
- NAIP | c.99G>T p.Q33H | Missense Mutation (SNP) | VAF 89/278 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.556); catalogued as COSV52002872; called by muse, mutect2, varscan2
- NALCN | c.3728C>A p.T1243K | Missense Mutation (SNP) | VAF 54/115 reads (47%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.811); catalogued as COSV51964895; called by muse, mutect2, varscan2
- NAT16 | c.962C>A p.A321D | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.219); catalogued as COSV55865676; called by muse, mutect2, varscan2
- NCKAP5 | c.3547G>T p.V1183L | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as rs377582875, COSV58474883; called by muse, mutect2, varscan2
- NCKAP5 | c.1005C>A p.S335R | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58474889; called by muse, mutect2, varscan2
- NDOR1 | c.128A>G p.Y43C | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.869); catalogued as COSV59178798; called by muse, mutect2
- NECAB2 | c.438G>T p.K146N | Missense Mutation (SNP) | VAF 102/183 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100533832, COSV59423427; called by muse, mutect2, varscan2
- NECAB2 | c.614C>A p.P205H | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as rs771258773, COSV59423440; called by muse, mutect2, varscan2
- NECTIN1 | c.1036G>T p.G346W | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); catalogued as COSV99872658; called by muse, mutect2, varscan2
- NELL1 | c.690C>A p.C230* | Nonsense Mutation (SNP) | VAF 53/92 reads (58%) | catalogued as COSV54324651; called by muse, mutect2, varscan2
- NES | c.1969G>T p.V657L | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.081); catalogued as COSV63962923; called by muse, mutect2, varscan2
- NEUROD2 | c.295G>T p.E99* | Nonsense Mutation (SNP) | VAF 5/19 reads (26%) | catalogued as COSV56911740; called by muse, mutect2, varscan2
- NF1 | c.8003T>A p.L2668Q (on ENST00000358273 / NM_001042492.3; = p.L2647Q on NM_000267.3) | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.363); catalogued as COSV62221568; called by muse, mutect2
- NF2 | c.1408C>T p.Q470* | Nonsense Mutation (SNP) | VAF 5/12 reads (42%) | catalogued as CM950858, COSV58520065, COSV58523542; called by muse, mutect2, varscan2
- NFASC | c.1314G>C p.Q438H (on ENST00000339876 / NM_001378329.1; = p.Q449H on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.063); catalogued as COSV58379992; called by muse, mutect2, varscan2
- NGB | c.392C>A p.A131D | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV53611984; called by muse, mutect2, varscan2
- NKX2-1 | c.424G>C p.G142R | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.254); catalogued as COSV61390262; called by muse, mutect2, varscan2
- NLRP12 | c.2563G>A p.V855I | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV60755294; called by muse, mutect2, varscan2
- NLRP13 | c.270G>T p.Q90H | Missense Mutation (SNP) | VAF 25/140 reads (18%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.615); catalogued as COSV61624061; called by muse, mutect2, varscan2
- NLRP8 | c.1022C>A p.T341K | Missense Mutation (SNP) | VAF 84/187 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV52593777; called by muse, mutect2, varscan2
- NNT | c.2668G>T p.G890* | Nonsense Mutation (SNP) | VAF 38/190 reads (20%) | catalogued as COSV52929695; called by muse, mutect2, varscan2
- NOD2 | c.1489C>A p.Q497K | Missense Mutation (SNP) | VAF 77/161 reads (48%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV56054822; called by muse, varscan2
- NOL9 | c.1921G>A p.G641R | Missense Mutation (SNP) | VAF 46/162 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66626963; called by muse, mutect2, varscan2
- NOTUM | c.1226G>A p.R409Q | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.776); catalogued as rs1482138833, COSV68826678; called by muse, mutect2
- NPFFR2 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.059); catalogued as COSV58154399; called by muse, mutect2, varscan2
- NPR3 | c.1169A>G p.Q390R | Missense Mutation (SNP) | VAF 78/237 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0.036); catalogued as rs373722650; called by muse, mutect2, varscan2
- NR4A3 | c.1471G>C p.D491H | Missense Mutation (SNP) | VAF 75/216 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); catalogued as COSV58248298; called by muse, mutect2, varscan2
- NRAP | c.4888C>A p.Q1630K (on ENST00000359988 / NM_001322945.2; = p.Q1595K on NM_006175.4) | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.146); catalogued as COSV100668106; called by muse, mutect2, varscan2
- NRXN1 | c.2878G>C p.G960R | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58493037; called by muse, mutect2, varscan2
- NTF3 | c.581G>C p.R194P | Missense Mutation (SNP) | VAF 66/162 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV58417437, COSV58418416; called by muse, mutect2, varscan2
- NTRK3 | c.1834C>G p.P612A | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as COSV62315183; called by muse, mutect2, varscan2
- NTRK3 | c.1304C>A p.A435E | Missense Mutation (SNP) | VAF 51/114 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV58142987; called by muse, mutect2, varscan2
- NTRK3 | c.688A>T p.T230S | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.57); PolyPhen benign (0.01); catalogued as COSV58143009; called by muse, mutect2, varscan2
- NUAK1 | c.554T>A p.L185Q | Missense Mutation (SNP) | VAF 45/87 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54608222; called by muse, mutect2, varscan2
- NUP153 | c.158G>T p.G53V | Missense Mutation (SNP) | VAF 193/297 reads (65%) | SIFT deleterious (0); PolyPhen benign (0.382); catalogued as COSV50465362; called by muse, mutect2, varscan2
- NUP205 | c.616A>G p.R206G | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs376210354; called by muse, mutect2, varscan2
- NUP205 | c.4897T>C p.S1633P | Missense Mutation (SNP) | VAF 56/192 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53665985; called by muse, mutect2, varscan2
- NXPH2 | c.665G>T p.W222L | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55646873; called by muse, mutect2, varscan2
- NXPH2 | c.488C>A p.P163H | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55640468, COSV55646885; called by muse, mutect2, varscan2
- OCA2 | c.1177G>T p.G393C | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV62358047; called by muse, mutect2, varscan2
- OPCML | c.291G>C p.Q97H | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as COSV59449990, COSV59452736; called by muse, mutect2, varscan2
- OPN4 | c.1297C>T p.Q433* | Nonsense Mutation (SNP) | VAF 8/23 reads (35%) | catalogued as COSV53949567; called by muse, mutect2, varscan2
- OR10A3 | c.169G>T p.V57F | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.304); catalogued as COSV62459338, COSV62460262; called by muse, mutect2, varscan2
- OR10A4 | c.722C>A p.T241N | Missense Mutation (SNP) | VAF 70/122 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65842508; called by muse, mutect2, varscan2
- OR10G2 | c.368T>A p.M123K | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV73390472; called by muse, varscan2
- OR10G8 | c.575C>A p.S192* | Nonsense Mutation (SNP) | VAF 34/166 reads (20%) | catalogued as COSV70909429; called by muse, mutect2, varscan2
- OR10H4 | c.673G>C p.A225P | Missense Mutation (SNP) | VAF 95/181 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.169); catalogued as COSV59063011; called by muse, mutect2, varscan2
- OR10P1 | c.221C>A p.T74N | Missense Mutation (SNP) | VAF 81/131 reads (62%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.722); catalogued as COSV59008455; called by muse, mutect2, varscan2
- OR13F1 | c.434C>A p.A145E | Missense Mutation (SNP) | VAF 50/107 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58252629; called by muse, mutect2, varscan2
- OR14A16 | c.909G>T p.K303N | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0.023); catalogued as rs995142044, COSV62927472; called by muse, mutect2, varscan2
- OR14K1 | c.475G>C p.A159P | Missense Mutation (SNP) | VAF 65/236 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV99315498; called by muse, mutect2, varscan2
- OR1A1 | c.491C>A p.A164D | Missense Mutation (SNP) | VAF 65/107 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV58404659; called by muse, mutect2, varscan2
- OR1J2 | c.810G>T p.K270N | Missense Mutation (SNP) | VAF 63/333 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.074); catalogued as COSV58945246; called by muse, varscan2
- OR1L8 | c.671C>A p.T224N | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.116); catalogued as COSV59187427; called by muse, mutect2, varscan2
- OR2A4 | c.625C>A p.P209T | Missense Mutation (SNP) | VAF 42/144 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV100199734; called by muse, varscan2
- OR2AK2 | c.400A>T p.M134L | Missense Mutation (SNP) | VAF 149/441 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs140557072, COSV63560833; called by muse, mutect2, varscan2
- OR2B11 | c.132G>T p.L44F | Missense Mutation (SNP) | VAF 77/216 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0.048); catalogued as COSV59511488; called by muse, mutect2, varscan2
- OR2B3 | c.511C>A p.H171N | Missense Mutation (SNP) | VAF 63/93 reads (68%) | SIFT tolerated (0.36); PolyPhen benign (0.345); catalogued as COSV65851191; called by muse, mutect2, varscan2
- OR2D2 | c.724G>T p.G242C | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55057976; called by muse, mutect2, varscan2
- OR2F2 | c.184T>C p.F62L | Missense Mutation (SNP) | VAF 116/416 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV68833372; called by muse, mutect2, varscan2
- OR2J3 | c.772del p.A258Pfs*34 | Frame Shift Del (DEL) | VAF 111/184 reads (60%) | catalogued as COSV65848962; called by mutect2, pindel*
- OR2L3 | c.893G>T p.G298V | Missense Mutation (SNP) | VAF 32/161 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as rs770970127, COSV100742059; called by muse, mutect2, varscan2
- OR2T2 | c.674C>G p.T225S | Missense Mutation (SNP) | VAF 43/76 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); catalogued as COSV61619063; called by muse, mutect2, varscan2
- OR2T3 | c.694A>T p.R232W | Missense Mutation (SNP) | VAF 66/298 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV62083700; called by muse, mutect2
- OR2T34 | c.694A>T p.R232W | Missense Mutation (SNP) | VAF 36/312 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV60901916; called by muse, mutect2, varscan2
- OR2T34 | c.38C>A p.A13E | Missense Mutation (SNP) | VAF 38/198 reads (19%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV60901925; called by muse, mutect2, varscan2
- OR4C3 | c.569C>A p.T190K | Missense Mutation (SNP) | VAF 43/120 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs79891698; called by muse, mutect2, varscan2
- OR4F4 | c.829C>A p.P277T | Missense Mutation (SNP) | VAF 176/627 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100055399; called by muse, mutect2, varscan2
- OR4P4 | c.40G>T p.G14W | Missense Mutation (SNP) | VAF 142/221 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100111725, COSV58923573; called by muse, mutect2, varscan2
- OR51E1 | c.387C>G p.I129M | Missense Mutation (SNP) | VAF 65/103 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67811011; called by muse, mutect2, varscan2
- OR52A5 | c.913C>A p.H305N | Missense Mutation (SNP) | VAF 47/89 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV56616728; called by muse, mutect2, varscan2
- OR52E6 | c.902G>T p.R301M | Missense Mutation (SNP) | VAF 68/128 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV61433390; called by muse, mutect2, varscan2
- OR52K1 | c.454G>T p.A152S | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.111); catalogued as COSV56904764, COSV56904978; called by muse, mutect2, varscan2
- OR52L1 | c.345C>A p.C115* | Nonsense Mutation (SNP) | VAF 23/43 reads (53%) | catalogued as COSV59989283; called by muse, mutect2, varscan2
- OR52M1 | c.747T>A p.C249* | Nonsense Mutation (SNP) | VAF 80/162 reads (49%) | catalogued as COSV64172829; called by muse, mutect2, varscan2
- OR5AS1 | c.163C>A p.L55I | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV57983221; called by muse, mutect2, varscan2
- OR5D16 | c.858G>T p.L286F | Missense Mutation (SNP) | VAF 46/96 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.344); catalogued as COSV101003878, COSV65721651; called by muse, mutect2, varscan2
- OR5F1 | c.838G>T p.V280L | Missense Mutation (SNP) | VAF 53/129 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.238); catalogued as COSV53548703; called by muse, mutect2, varscan2
- OR5K3 | c.257T>A p.F86Y | Missense Mutation (SNP) | VAF 306/506 reads (60%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.703); catalogued as COSV67350704; called by muse, mutect2, varscan2
- OR5T1 | c.736A>T p.R246W | Missense Mutation (SNP) | VAF 70/324 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.286); catalogued as COSV57304866; called by muse, mutect2, varscan2
- OR6B1 | c.428G>T p.R143L | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated (0.51); PolyPhen benign (0.027); catalogued as COSV68770655; called by muse, mutect2, varscan2
- OR6C65 | c.784G>C p.A262P | Missense Mutation (SNP) | VAF 79/146 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.495); catalogued as COSV65569421; called by muse, mutect2, varscan2
- OR6K6 | c.578C>G p.T193S (on ENST00000368144; = p.T169S on NM_001005184.1) | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.85); catalogued as COSV63744902; called by muse, mutect2, varscan2
- OR7D4 | c.787G>T p.A263S | Missense Mutation (SNP) | VAF 59/100 reads (59%) | SIFT tolerated (0.1); PolyPhen benign (0.07); catalogued as COSV58072593; called by muse, mutect2, varscan2
- OR8D2 | c.566G>T p.C189F | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62489036; called by muse, mutect2, varscan2
- OR8H1 | c.883G>T p.E295* | Nonsense Mutation (SNP) | VAF 105/266 reads (39%) | catalogued as rs761763741, COSV57295920; called by muse, mutect2, varscan2
- OR8J3 | c.479C>T p.S160L | Missense Mutation (SNP) | VAF 28/142 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as COSV56880195, COSV56880522; called by muse, mutect2, varscan2
- OSR2 | c.255C>G p.F85L | Missense Mutation (SNP) | VAF 63/162 reads (39%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); catalogued as COSV52558987; called by muse, mutect2, varscan2
- OSR2 | c.909C>A p.S303R (on ENST00000297565 / NM_001142462.3; = p.A276D on NM_053001.3) | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (1); PolyPhen possibly damaging (0.727); catalogued as COSV52559000; called by muse, mutect2
- OTOF | c.2822G>T p.G941V (on ENST00000272371 / NM_194248.3; = p.G194V on NM_004802.4) | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.796); catalogued as COSV55519577; called by muse, mutect2, varscan2
- OTOF | c.951C>G p.I317M | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); catalogued as CM1515083, COSV55519612; called by muse, mutect2, varscan2
- OTUD7B | c.172G>C p.E58Q | Missense Mutation (SNP) | VAF 64/149 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.715); catalogued as COSV64917753; called by muse, mutect2, varscan2
- OVCH1 | c.324C>G p.S108R | Missense Mutation (SNP) | VAF 49/253 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV58968090; called by muse, mutect2, varscan2
- OXSR1 | c.919A>T p.R307* | Nonsense Mutation (SNP) | VAF 97/157 reads (62%) | catalogued as COSV61260620; called by muse, mutect2, varscan2
- P2RY14 | c.921T>A p.C307* | Nonsense Mutation (SNP) | VAF 128/273 reads (47%) | catalogued as COSV56397067; called by muse, mutect2, varscan2
- PAFAH1B2 | c.220G>T p.G74W | Missense Mutation (SNP) | VAF 41/150 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV59167598; called by muse, mutect2, varscan2
- PAK1 | c.223A>T p.I75F | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53701372; called by muse, mutect2, varscan2
- PALM | c.761C>A p.A254E | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.254); catalogued as COSV52771032; called by muse, mutect2
- PAMR1 | c.397del p.R133Efs*14 | Frame Shift Del (DEL) | VAF 15/131 reads (11%) | catalogued as COSV53512436; called by mutect2, pindel, varscan2
- PASK | c.2092G>C p.D698H | Missense Mutation (SNP) | VAF 67/177 reads (38%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.758); catalogued as COSV52160395; called by muse, mutect2, varscan2
- PATJ | c.5059C>G p.L1687V | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV64506707; called by muse, mutect2, varscan2
- PAX2 | c.1148del p.A383Vfs*10 (on ENST00000428433 / NM_003987.5; = p.A360Vfs*10 on NM_000278.5 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 16/85 reads (19%) | catalogued as COSV62290239; called by mutect2, pindel*, varscan2
- PAX4 | c.583C>A p.P195T | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58388404, COSV58389822, COSV58391280; called by muse, mutect2, varscan2
- PCDH15 | c.2650G>C p.A884P | Missense Mutation (SNP) | VAF 47/264 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.555); catalogued as COSV57393223; called by muse, mutect2, varscan2
- PCDH15 | c.130G>A p.V44I | Missense Mutation (SNP) | VAF 29/176 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.474); catalogued as COSV57393262; called by muse, mutect2, varscan2
- PCDH9 | c.3251T>C p.L1084P (on ENST00000377865 / NM_203487.3; = p.L1050P on NM_020403.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 67/130 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV60589819; called by muse, mutect2, varscan2
- PCDHA1 | c.674C>T p.T225I | Missense Mutation (SNP) | VAF 50/95 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.73); catalogued as COSV65376992; called by muse, mutect2
- PCDHA1 | c.676G>A p.V226I | Missense Mutation (SNP) | VAF 50/93 reads (54%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.367); catalogued as COSV65376996; called by muse, mutect2
- PCDHA1 | c.1461C>A p.N487K | Missense Mutation (SNP) | VAF 65/132 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100974412, COSV65376998; called by muse, mutect2, varscan2
- PCDHA2 | c.1377G>T p.E459D | Missense Mutation (SNP) | VAF 63/117 reads (54%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.065); catalogued as COSV65371100; called by muse, mutect2, varscan2
- PCDHA4 | c.1252G>T p.V418L | Missense Mutation (SNP) | VAF 96/213 reads (45%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.113); catalogued as COSV63543546, COSV63544408, COSV63546038; called by muse, mutect2, varscan2
- PCDHA5 | c.1367A>G p.Q456R | Missense Mutation (SNP) | VAF 61/124 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.516); catalogued as COSV65357838; called by muse, mutect2, varscan2
- PCDHA7 | c.389C>A p.P130H | Missense Mutation (SNP) | VAF 112/238 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.457); catalogued as COSV100971851; called by muse, varscan2
- PCDHAC1 | c.2467G>T p.A823S | Missense Mutation (SNP) | VAF 42/83 reads (51%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.54); catalogued as COSV53869518; called by muse, mutect2, varscan2
- PCDHB13 | c.722C>T p.P241L | Missense Mutation (SNP) | VAF 91/201 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV53401034; called by muse, mutect2, varscan2
- PCDHGA2 | c.1876G>T p.V626L | Missense Mutation (SNP) | VAF 58/110 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.327); catalogued as rs762713317, COSV54032525, COSV99549413; called by muse, mutect2, varscan2
- PCDHGA8 | c.1909G>C p.A637P | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.908); catalogued as COSV53938425, COSV54032557; called by muse, mutect2, varscan2
- PCLO | c.4003G>T p.G1335W | Missense Mutation (SNP) | VAF 28/143 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV61678896; called by muse, mutect2, varscan2
- PCNX1 | c.2779-1G>T p.X927_splice | Splice Site (SNP) | VAF 57/143 reads (40%) | catalogued as COSV53101785; called by muse, mutect2, varscan2
- PDCD11 | c.2098G>T p.G700W | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.599); catalogued as COSV63935337; called by muse, mutect2, varscan2
- PDCD11 | c.2099G>T p.G700V | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.265); catalogued as COSV63935342; called by muse, mutect2, varscan2
- PDCD6IP | c.869G>T p.R290L | Missense Mutation (SNP) | VAF 107/208 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.177); catalogued as COSV56245630; called by muse, mutect2, varscan2
- PDE4DIP | c.5165G>T p.S1722I | Missense Mutation (SNP) | VAF 94/225 reads (42%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.875); catalogued as COSV57728077; called by muse, mutect2, varscan2
- PDE6A | c.2323G>T p.G775C | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54930095, COSV54931269; called by muse, mutect2, varscan2
- PDE8B | c.1552G>A p.G518R | Missense Mutation (SNP) | VAF 59/104 reads (57%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); catalogued as COSV53742920; called by muse, mutect2, varscan2
- PDGFRB | c.2123G>T p.R708L | Missense Mutation (SNP) | VAF 71/141 reads (50%) | SIFT tolerated (0.38); PolyPhen benign (0.139); catalogued as COSV55810047; called by muse, mutect2, varscan2
- PDK3 | c.700G>C p.V234L | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as COSV64794442; called by muse, mutect2, varscan2
- PDS5A | c.2531G>T p.R844M | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57831221; called by muse, mutect2, varscan2
- PDZD2 | c.1387A>T p.S463C | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV56872479; called by muse, mutect2, varscan2
- PDZD2 | c.1388G>A p.S463N | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.014); catalogued as COSV56872499; called by muse, mutect2, varscan2
- PDZD8 | c.1867G>A p.V623M | Missense Mutation (SNP) | VAF 80/188 reads (43%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as rs114690685, COSV57828567; called by muse, mutect2, varscan2
- PGPEP1 | c.505G>T p.V169L | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53253011; called by muse, mutect2, varscan2
- PGR | c.2104G>T p.G702* | Nonsense Mutation (SNP) | VAF 61/293 reads (21%) | catalogued as COSV54795898, COSV54810645; called by muse, mutect2, varscan2
- PHACTR3 | c.475G>A p.A159T | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.162); catalogued as COSV63034213; called by muse, mutect2, varscan2
- PHB | c.511-1G>C p.X171_splice | Splice Site (SNP) | VAF 17/49 reads (35%) | catalogued as COSV55931820; called by muse, mutect2, varscan2
- PHF12 | c.623G>T p.R208L | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.605); catalogued as COSV99256264; called by muse, mutect2
- PHLPP1 | c.1949A>T p.E650V | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.88); catalogued as COSV53038380; called by muse, mutect2, varscan2
- PIEZO2 | c.6849G>A p.E2283= | Splice Region (SNP) | VAF 92/223 reads (41%) | catalogued as COSV53292206, COSV53294145; called by muse, mutect2, varscan2
- PIGO | c.1981G>T p.V661L | Missense Mutation (SNP) | VAF 66/103 reads (64%) | SIFT tolerated (0.17); PolyPhen benign (0.02); catalogued as COSV53055417; called by muse, mutect2, varscan2
- PIK3CG | c.1441G>T p.V481F | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as COSV63252383, COSV63253560; called by muse, mutect2, varscan2
- PITPNM3 | c.1726G>C p.A576P | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52600078; called by muse, mutect2, varscan2
- PITX1 | c.439C>A p.R147S | Missense Mutation (SNP) | VAF 61/126 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV54762458, COSV54762972; called by muse, mutect2, varscan2
- PKN1 | c.1559G>T p.R520L | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.169); catalogued as COSV54403884; called by muse, mutect2, varscan2
- PLA2G4A | c.1417G>T p.V473L | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as COSV66556932; called by muse, mutect2, varscan2
- PLCE1 | c.1315G>T p.G439C | Missense Mutation (SNP) | VAF 56/138 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.72); catalogued as COSV53356872; called by muse, mutect2, varscan2
- PLCH1 | c.4480A>G p.S1494G (on ENST00000340059 / NM_001130960.2; = p.S1486G on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58210171; called by muse, mutect2, varscan2
- PLCXD2 | c.389T>C p.F130S | Missense Mutation (SNP) | VAF 171/252 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67342206; called by muse, mutect2, varscan2
- PLEKHH2 | c.1993G>A p.E665K | Missense Mutation (SNP) | VAF 54/335 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV56757971; called by muse, mutect2, varscan2
- PLPP4 | c.617-2A>G p.X206_splice | Splice Site (SNP) | VAF 51/248 reads (21%) | catalogued as COSV64829715; called by muse, mutect2, varscan2
- PLPP7 | c.56G>T p.R19L | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.195); catalogued as COSV64836235; called by muse, mutect2, varscan2
- PMFBP1 | c.409G>A p.D137N | Missense Mutation (SNP) | VAF 139/245 reads (57%) | SIFT deleterious (0.05); PolyPhen benign (0.067); catalogued as COSV52832196; called by muse, mutect2, varscan2
- PMVK | c.125G>T p.R42L | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV63786170; called by muse, mutect2, varscan2
- PNCK | c.416C>A p.P139H (on ENST00000340888 / NM_001366975.1; = p.P222H on NM_001039582.3) | Missense Mutation (SNP) | VAF 80/129 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61745448; called by muse, mutect2, varscan2
- PNPLA8 | c.1358G>T p.R453M | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57554768; called by muse, mutect2, varscan2
- POMT1 | c.1868G>A p.R623K | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.339); catalogued as CM074444, COSV61227805; called by muse, mutect2, varscan2
- POTEH | c.405G>T p.M135I | Missense Mutation (SNP) | VAF 84/538 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.049); catalogued as COSV58886982; called by muse, varscan2
- PPARGC1A | c.1994G>T p.R665M | Missense Mutation (SNP) | VAF 35/167 reads (21%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.984); catalogued as COSV99338699; called by muse, mutect2, varscan2
- PPEF2 | c.1483T>A p.Y495N | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54426291; called by muse, mutect2, varscan2
- PPIAL4G | c.362G>A p.W121* | Nonsense Mutation (SNP) | VAF 39/182 reads (21%) | catalogued as COSV70087551; called by muse, mutect2, varscan2
- PPM1D | c.727C>T p.R243C | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59955334; called by muse, mutect2, varscan2
- PPP1R35 | c.83C>A p.P28H | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52770002; called by muse, mutect2
- PRCP | c.1336G>C p.V446L | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV57291716; called by muse, mutect2, varscan2
- PRDM1 | c.1159G>T p.G387C | Missense Mutation (SNP) | VAF 51/103 reads (50%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.987); catalogued as COSV64847025; called by muse, mutect2, varscan2
- PRDM9 | c.98T>A p.I33K | Missense Mutation (SNP) | VAF 114/390 reads (29%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.525); catalogued as COSV57013211; called by muse, mutect2, varscan2
- PRDM9 | c.765G>T p.Q255H | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.496); catalogued as COSV57008169; called by muse, mutect2, varscan2
- PRG4 | c.1523C>A p.P508H | Missense Mutation (SNP) | VAF 60/206 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV63356482; called by muse, mutect2, varscan2
- PRICKLE2 | c.929A>T p.Y310F (on ENST00000295902; = p.Y254F on NM_198859.4) | Missense Mutation (SNP) | VAF 108/214 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as COSV55771731; called by muse, mutect2, varscan2
- PRKAG3 | c.358G>T p.D120Y | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.707); catalogued as COSV52103795; called by muse, mutect2, varscan2
- PRKCQ | c.1429G>T p.D477Y | Missense Mutation (SNP) | VAF 214/519 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV54119052; called by muse, mutect2, varscan2
- PRMT3 | c.1477G>C p.V493L | Missense Mutation (SNP) | VAF 115/208 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as COSV58180789; called by muse, mutect2, varscan2
- PROX2 | c.47C>G p.S16C | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as COSV71520194; called by muse, mutect2, varscan2
- PRRX1 | c.514G>T p.V172L | Missense Mutation (SNP) | VAF 44/126 reads (35%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.872); catalogued as COSV53411819, COSV53419050; called by muse, mutect2, varscan2
- PRXL2A | c.316G>T p.G106C | Missense Mutation (SNP) | VAF 35/178 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64691234; called by muse, mutect2, varscan2
- PSG2 | c.962C>T p.S321F | Missense Mutation (SNP) | VAF 72/394 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.08); catalogued as COSV61546547; called by muse, mutect2, varscan2
- PSG6 | c.524C>A p.A175E | Missense Mutation (SNP) | VAF 76/341 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as rs1174096642, COSV51837844; called by muse, mutect2, varscan2
- PSG7 | c.641C>A p.P214H | Missense Mutation (SNP) | VAF 116/626 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV68446601; called by muse, mutect2, varscan2
- PTCHD3 | c.226C>T p.P76S | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.026); catalogued as COSV71257233; called by muse, mutect2, varscan2
- PTGS1 | c.1234A>T p.M412L | Missense Mutation (SNP) | VAF 35/173 reads (20%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV56294740; called by muse, mutect2, varscan2
- PTPN12 | c.220C>T p.R74* | Nonsense Mutation (SNP) | VAF 22/132 reads (17%) | catalogued as COSV50371805; called by muse, mutect2, varscan2
728 further variants in this file (386 protein-altering or splice-affecting, 301 silent, 41 other) are not listed here.
